Somatic mutation profile of tumor specimen TCGA-D1-A17H-01A (aliquot TCGA-D1-A17H-01A-11D-A12J-09) from TCGA case TCGA-D1-A17H, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G1; Age at diagnosis: 61.3 years (22,389 days).
Specimen TCGA-D1-A17H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c87f5ff8-076a-4903-9a22-d193cb922ef1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A17H-10A (Blood Derived Normal), aliquot TCGA-D1-A17H-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59bbabee-b36a-44f8-b5c4-22c9497dc34f

The open-access MAF lists 811 somatic variants for this specimen: 626 protein-altering or splice-affecting, 170 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 379, Silent 170, Frame Shift Del 145, Frame Shift Ins 39, Nonsense Mutation 24, Splice Site 20, In Frame Del 12, Splice Region 7, Intron 6, 3'UTR 4, RNA 2, 5'Flank 2.

Variants (750 of 811; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.6472C>T p.R2158* | Nonsense Mutation (SNP) | VAF 23/56 reads (41%) | hotspot (GDC flag); catalogued as COSV61370611, COSV61381711; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 66/214 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MYO6 | c.2751del p.K917Nfs*10 | Frame Shift Del (DEL) | VAF 39/168 reads (23%) | catalogued as rs551348450; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- PEX1 | c.1108del p.I370Lfs*17 | Frame Shift Del (DEL) | VAF 44/112 reads (39%) | catalogued as rs61750406; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 38/117 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RAD50 | c.2801dup p.N934Kfs*10 | Frame Shift Ins (INS) | VAF 76/235 reads (32%) | catalogued as rs748536322; ClinVar: pathogenic; called by mutect2, varscan2
- ABCA1 | c.4552G>A p.A1518T | Missense Mutation (SNP) | VAF 96/263 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV66065531; called by muse, mutect2, varscan2
- ABCC6 | c.573del p.F192Sfs*40 | Frame Shift Del (DEL) | VAF 13/65 reads (20%) | catalogued as rs1172142986; called by mutect2, varscan2
- ACIN1 | c.3970C>T p.H1324Y | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV52975346; called by muse, varscan2
- ACO2 | c.2239G>A p.G747R | Missense Mutation (SNP) | VAF 106/268 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs768151174, COSV53442399, COSV99347248; called by muse, mutect2, varscan2
- ACOX2 | c.1826A>G p.Y609C | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV57148535; called by muse, mutect2, varscan2
- ACOX3 | c.1975G>A p.D659N | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.665); catalogued as rs550313569, COSV62711558; called by muse, mutect2, varscan2
- ACSL4 | c.1821-3dup | Splice Region (INS) | VAF 31/146 reads (21%) | catalogued as rs748641243; called by mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 56/156 reads (36%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM19 | c.772G>A p.V258M | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1269548513, COSV57424841; called by muse, mutect2, varscan2
- ADAMTS13 | c.3682C>T p.R1228C | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs148824378; called by muse, mutect2, varscan2
- ADAMTS18 | c.2085del p.F695Lfs*7 | Frame Shift Del (DEL) | VAF 75/248 reads (30%) | catalogued as rs772504358, COSV51414270; called by mutect2, varscan2
- ADAMTS7 | c.2646-1G>A p.X882_splice | Splice Site (SNP) | VAF 14/27 reads (52%) | catalogued as COSV66306781; called by muse, varscan2
- ADAMTSL1 | c.4123dup p.Q1375Pfs*53 | Frame Shift Ins (INS) | VAF 46/130 reads (35%) | catalogued as rs758913277; called by mutect2, varscan2
- ADCY7 | c.2522T>C p.M841T | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV54265957; called by muse, mutect2, varscan2
- AEBP1 | c.1885G>T p.V629L | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV56257016; called by muse, mutect2, varscan2
- AGBL4 | c.556_557del p.M186Gfs*18 | Frame Shift Del (DEL) | VAF 48/153 reads (31%) | catalogued as COSV65735730; called by mutect2, pindel, varscan2
- AGBL5 | c.909-1G>A p.X303_splice | Splice Site (SNP) | VAF 15/48 reads (31%) | catalogued as COSV59936320; called by muse, mutect2, varscan2
- ALDH1L2 | c.1408A>T p.T470S | Missense Mutation (SNP) | VAF 58/243 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV51554989; called by muse, mutect2, varscan2
- ALKBH5 | c.1072C>T p.R358W | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs762603610, COSV67686922; called by muse, mutect2, varscan2
- ALMS1 | c.11033G>T p.R3678L | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.392); catalogued as COSV52507926; called by muse, mutect2, varscan2
- ALOXE3 | c.2066G>T p.R689L | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59075166; called by muse, mutect2
- AMY2A | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 29/513 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1209825158, COSV70214423; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.1215G>A p.M405I | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.968); catalogued as rs1273794729, COSV51842805; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5944A>G p.T1982A | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV51845209; called by muse, mutect2, varscan2
- ANKRD17 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 65/186 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1431668635, COSV58218767; called by muse, mutect2, varscan2
- ANKRD30A | c.337-2A>G p.X113_splice (on ENST00000611781; = p.X57_splice on NM_052997.2) | Splice Site (SNP) | VAF 38/92 reads (41%) | catalogued as rs1410048229, COSV64608489; called by muse, mutect2, varscan2
- ANKRD35 | c.1504G>A p.V502M | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV62910093; called by muse, mutect2
- AP2A2 | c.2627C>T p.A876V | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.982); catalogued as COSV59959752; called by muse, mutect2, varscan2
- APIP | c.283del p.S95Afs*8 | Frame Shift Del (DEL) | VAF 96/382 reads (25%) | catalogued as rs546686089; called by mutect2, varscan2
- APOB | c.3716A>G p.Q1239R | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV51931924; called by muse, mutect2, varscan2
- APOBEC2 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs760829942, COSV55142479; called by muse, mutect2, varscan2
- ARHGAP32 | c.878del p.P293Rfs*4 | Frame Shift Del (DEL) | VAF 77/232 reads (33%) | catalogued as rs1565402836; called by mutect2, pindel, varscan2
- ARHGAP44 | c.2004C>A p.D668E | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs374439788, COSV99310846; called by muse, mutect2, varscan2
- ARHGEF39 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT tolerated (1); PolyPhen possibly damaging (0.476); catalogued as COSV58396900; called by muse, mutect2, varscan2
- ARID4B | c.2299G>A p.A767T | Missense Mutation (SNP) | VAF 90/275 reads (33%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV51601778; called by muse, mutect2, varscan2
- ARID5B | c.1489del p.I497* | Frame Shift Del (DEL) | VAF 46/156 reads (29%) | catalogued as rs201178069; called by mutect2, pindel, varscan2
- ARRB2 | c.779+3_779+6del p.X260_splice | Splice Site (DEL) | VAF 6/34 reads (18%) | catalogued as rs1326616072; called by pindel, varscan2
- ARSH | c.1220T>C p.L407P | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771393827, COSV66962816; called by muse, mutect2, varscan2
- ASPM | c.3515C>T p.T1172M | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as rs201067420, COSV54128368; called by muse, mutect2, varscan2
- ATAD3A | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.899); catalogued as COSV59232944; called by muse, mutect2, varscan2
- ATG12 | c.380G>T p.G127V | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57242971; called by muse, varscan2
- ATG16L1 | c.1180A>G p.T394A (on ENST00000392017 / NM_030803.7; = p.T375A on NM_017974.4) | Missense Mutation (SNP) | VAF 96/279 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as COSV61465187; called by muse, mutect2, varscan2
- ATL2 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.209); catalogued as COSV60051346; called by muse, mutect2, varscan2
- ATN1 | c.764del p.P255Hfs*43 | Frame Shift Del (DEL) | VAF 4/16 reads (25%) | catalogued as rs1555143544, COSV63112070; called by mutect2, varscan2
- ATP10B | c.2014G>T p.G672C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV59149003; called by muse, mutect2, varscan2
- ATP10D | c.2444G>A p.S815N | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as COSV56706554; called by muse, mutect2, varscan2
- ATP2C2 | c.1555T>C p.Y519H | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV52294745; called by muse, mutect2
- ATP4B | c.581G>A p.G194D | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.254); catalogued as rs776175770, COSV58928792; called by muse, mutect2, varscan2
- BACE1 | c.1387G>A p.A463T | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.856); catalogued as COSV56118424; called by muse, mutect2, varscan2
- BAG1 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.379); catalogued as rs367820745, COSV65651567; called by muse, mutect2, varscan2
- BNIP5 | c.1702dup p.Y568Lfs*24 | Frame Shift Ins (INS) | VAF 34/86 reads (40%) | catalogued as rs747868798; called by mutect2, varscan2
- BRINP3 | c.1882T>C p.Y628H | Missense Mutation (SNP) | VAF 67/203 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66520595; called by muse, mutect2, varscan2
- BTAF1 | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 90/176 reads (51%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV56432457; called by muse, mutect2, varscan2
- C1QTNF3 | c.506T>C p.M169T | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as COSV51468345; called by muse, mutect2
- C4orf17 | c.253del p.S85Pfs*10 | Frame Shift Del (DEL) | VAF 44/153 reads (29%) | catalogued as rs201447915; called by mutect2, pindel, varscan2
- C6orf201 | c.302del p.N101Mfs*8 | Frame Shift Del (DEL) | VAF 46/148 reads (31%) | catalogued as rs1438775096; called by mutect2, pindel, varscan2
- C6orf62 | c.429+1G>A p.X143_splice | Splice Site (SNP) | VAF 7/141 reads (5%) | catalogued as COSV65290347; called by muse, mutect2
- CAD | c.2089G>A p.A697T | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53025735; called by muse, mutect2, varscan2
- CALN1 | c.547C>A p.Q183K (on ENST00000329008 / NM_001017440.3; = p.Q225K on NM_031468.4) | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV100208729, COSV61128166; called by muse, mutect2, varscan2
- CAPN6 | c.597G>A p.M199I | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV60694626; called by muse, mutect2, varscan2
- CAPN7 | c.1316C>T p.A439V | Missense Mutation (SNP) | VAF 7/177 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1405805187, COSV53777795; called by muse, mutect2
- CARD6 | c.2320G>A p.A774T | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54565683, COSV54569371; called by muse, mutect2, varscan2
- CARMIL1 | c.2174G>A p.R725H | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs74654931; called by muse, mutect2, varscan2
- CBLL2 | c.902A>G p.Q301R | Missense Mutation (SNP) | VAF 11/155 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV60368806; called by muse, mutect2
- CCAR2 | c.4T>C p.S2P | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.939); catalogued as COSV51515005; called by muse, mutect2, varscan2
- CCDC138 | c.152-1G>T p.X51_splice | Splice Site (SNP) | VAF 22/448 reads (5%) | catalogued as COSV51699612; called by muse, mutect2
- CCDC39 | c.431A>G p.E144G | Missense Mutation (SNP) | VAF 19/290 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56482305; called by muse, mutect2
- CCDC51 | c.110G>A p.C37Y | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV56488763; called by muse, mutect2, varscan2
- CCDC73 | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 55/159 reads (35%) | catalogued as COSV58797554; called by muse, mutect2, varscan2
- CCNB3 | c.607G>T p.D203Y | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV52072391; called by muse, mutect2, varscan2
- CCNT2 | c.2104G>A p.E702K | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.022); catalogued as rs190052933, COSV51472489; called by muse, mutect2, varscan2
- CD300LB | c.326G>T p.R109I | Missense Mutation (SNP) | VAF 21/219 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV58725550; called by muse, mutect2, varscan2
- CDC23 | c.266T>C p.L89P | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV67508384; called by muse, mutect2, varscan2
- CDC42BPB | c.5033C>T p.T1678I | Missense Mutation (SNP) | VAF 63/206 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); catalogued as COSV54486520; called by muse, mutect2, varscan2
- CDH7 | c.1489G>T p.G497W | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59884595, COSV59893215; called by muse, mutect2, varscan2
- CDON | c.2189C>T p.S730F | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54997054; called by muse, mutect2, varscan2
- CEBPZ | c.2885-3del | Splice Region (DEL) | VAF 22/63 reads (35%) | catalogued as rs375852685; called by mutect2, varscan2
- CELA3A | c.451C>A p.L151I | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51582975; called by muse, mutect2, varscan2
- CEMIP2 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs149563104; called by muse, mutect2, varscan2
- CEP192 | c.6392C>T p.T2131I | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV58062754; called by muse, mutect2, varscan2
- CEP76 | c.295del p.T99Lfs*90 | Frame Shift Del (DEL) | VAF 30/75 reads (40%) | catalogued as rs747064410; called by mutect2, varscan2
- CEP78 | c.1457A>G p.E486G (on ENST00000424347 / NM_001349840.2; = p.E487G on NM_032171.3) | Missense Mutation (SNP) | VAF 67/184 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV52846792; called by muse, mutect2, varscan2
- CEP85L | c.1930C>T p.L644F | Missense Mutation (SNP) | VAF 64/178 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV63822270; called by muse, mutect2, varscan2
- CFL2 | c.410T>C p.V137A | Missense Mutation (SNP) | VAF 57/209 reads (27%) | SIFT tolerated (0.88); PolyPhen benign (0.019); catalogued as COSV53311379; called by muse, mutect2, varscan2
- CHST1 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as COSV57323162; called by muse, mutect2
- CIB3 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs186929589, COSV54165957; called by muse, mutect2, varscan2
- CLIP3 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV62112303; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 18/165 reads (11%) | catalogued as rs369752219; called by mutect2, varscan2
- CMTM6 | c.213del p.F71Lfs*4 | Frame Shift Del (DEL) | VAF 59/180 reads (33%) | catalogued as rs1167303901; called by mutect2, pindel, varscan2
- CNBD2 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 79/223 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as rs200885142, COSV62586786; called by muse, mutect2, varscan2
- CNTN1 | c.2528G>A p.R843Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs547467864, COSV61638757, COSV61642076; called by muse, mutect2
- CNTN3 | c.832T>A p.F278I | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV55168526; called by muse, mutect2, varscan2
- CNTNAP2 | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 17/243 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0.06); catalogued as rs1329353667, COSV62168245; ClinVar: uncertain significance; called by muse, mutect2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 26/50 reads (52%) | catalogued as rs374805044; called by mutect2, varscan2
- COL19A1 | c.1929G>T p.Q643H | Missense Mutation (SNP) | VAF 95/291 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV59570573; called by muse, mutect2, varscan2
- COL20A1 | c.2107G>A p.V703I | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs757858672, COSV58915272; called by muse, mutect2, varscan2
- COL22A1 | c.2472del p.G825Vfs*8 | Frame Shift Del (DEL) | VAF 51/154 reads (33%) | catalogued as COSV57350297; called by mutect2, pindel, varscan2
- COL2A1 | c.4132C>A p.L1378I | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV61529710; called by muse, mutect2, varscan2
- COL6A2 | c.1459-1G>T p.X487_splice | Splice Site (SNP) | VAF 6/39 reads (15%) | catalogued as COSV56003117; called by muse, mutect2, varscan2
- COL6A6 | c.4613G>A p.W1538* | Nonsense Mutation (SNP) | VAF 8/77 reads (10%) | catalogued as COSV62022808; called by muse, mutect2, varscan2
- COL7A1 | c.4127del p.P1376Lfs*23 | Frame Shift Del (DEL) | VAF 20/65 reads (31%) | catalogued as rs757976973; called by mutect2, pindel, varscan2
- COL9A3 | c.1315G>A p.G439R | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59652064; called by muse, mutect2, varscan2
- COPA | c.1532T>A p.I511N | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV54101268; called by muse, mutect2, varscan2
- CPT1B | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs150309698; called by muse, mutect2, varscan2
- CPVL | c.668T>C p.V223A | Missense Mutation (SNP) | VAF 65/196 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs750639311, COSV55301501; called by muse, mutect2, varscan2
- CRACD | c.2237G>A p.R746Q | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.526); catalogued as rs1267087805, COSV51719378; called by muse, mutect2, varscan2
- CREG2 | c.521A>G p.Y174C | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1373381551, COSV61316521; called by muse, mutect2, varscan2
- CRYGS | c.412A>T p.I138F | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57192314; called by muse, mutect2, varscan2
- CSDE1 | c.1534C>T p.R512C (on ENST00000358528 / NM_001007553.3; = p.R481C on NM_007158.6) | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs1379534757, COSV54744086; called by muse, mutect2, varscan2
- CSGALNACT1 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as rs377594341; called by muse, mutect2, varscan2
- CSNK1G3 | c.145del p.I49Lfs*11 | Frame Shift Del (DEL) | VAF 30/126 reads (24%) | catalogued as rs775129818, COSV62054115, COSV62057434; called by mutect2, varscan2
- CSNK2A2 | c.318+2T>C p.X106_splice | Splice Site (SNP) | VAF 64/214 reads (30%) | catalogued as COSV52641701; called by muse, mutect2, varscan2
- CTNNA3 | c.2568dup p.P857Tfs*4 | Frame Shift Ins (INS) | VAF 50/162 reads (31%) | catalogued as rs759618368; called by mutect2, varscan2
- CUL3 | c.2133G>A p.M711I | Missense Mutation (SNP) | VAF 34/615 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52362424, COSV52363774; called by muse, mutect2
- CYB5B | c.73A>G p.T25A | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.121); catalogued as COSV57174421; called by muse, mutect2, varscan2
- CYFIP2 | c.3196C>T p.R1066C (on ENST00000616178 / NM_001291722.2; = p.R1041C on NM_014376.4) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.684); catalogued as rs763607353, COSV100557783, COSV59034515; called by muse, mutect2, varscan2
- CYP27B1 | c.1370G>C p.G457A | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV56984581; called by muse, mutect2, varscan2
- CYP2A13 | c.233T>A p.V78D | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57837206; called by muse, mutect2
- CYP4F22 | c.446G>A p.G149D | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs751335732, COSV54107918; called by muse, mutect2, varscan2
- DAPK1 | c.1351G>A p.V451M | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs759240509, COSV63786451; called by muse, mutect2, varscan2
- DCC | c.1479G>T p.K493N | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.193); catalogued as COSV59097617, COSV59139949; called by muse, mutect2, varscan2
- DCUN1D3 | c.85C>T p.H29Y | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.14); catalogued as rs1163787576, COSV60953057; called by muse, mutect2, varscan2
- DCX | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 87/280 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as COSV57568254; called by muse, mutect2, varscan2
- DDX10 | c.1001G>A p.C334Y | Missense Mutation (SNP) | VAF 13/238 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59433747; called by muse, mutect2
- DENND4B | c.4280G>T p.R1427M | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63408523; called by muse, mutect2, varscan2
- DENND6A | c.1074del p.F358Lfs*14 | Frame Shift Del (DEL) | VAF 87/370 reads (24%) | catalogued as rs34959359; called by mutect2, varscan2
- DGCR2 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.614); catalogued as rs767702771, COSV54217873; called by muse, mutect2, varscan2
- DHX36 | c.2900T>C p.V967A | Missense Mutation (SNP) | VAF 21/263 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.441); catalogued as COSV57671006; called by muse, mutect2
- DHX37 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV58133720; called by muse, mutect2, varscan2
- DLST | c.1126G>A p.V376I | Missense Mutation (SNP) | VAF 138/339 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.404); catalogued as rs368230665; called by muse, mutect2, varscan2
- DMWD | c.738_739insA p.C247Mfs*38 | Frame Shift Ins (INS) | VAF 6/18 reads (33%) | catalogued as COSV99353365; called by mutect2, varscan2
- DMXL1 | c.2455A>G p.I819V | Missense Mutation (SNP) | VAF 6/154 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV60709361; called by muse, mutect2
- DNAAF1 | c.440T>C p.L147P | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57576945; called by muse, mutect2, varscan2
- DNAH3 | c.5899A>G p.I1967V | Missense Mutation (SNP) | VAF 89/287 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs193244009, COSV54516084; called by muse, mutect2, varscan2
- DNAH3 | c.3977G>A p.R1326Q | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs569588749, COSV54516105; called by muse, mutect2, varscan2
- DNAH5 | c.10657C>T p.R3553W | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs754263109, COSV54218517, COSV99443101; called by muse, mutect2, varscan2
- DNAH7 | c.3770del p.N1257Ifs*11 | Frame Shift Del (DEL) | VAF 56/162 reads (35%) | catalogued as rs34468832; called by mutect2, varscan2
- DNAJA2 | c.926T>A p.V309D | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV57694652; called by muse, mutect2, varscan2
- DNHD1 | c.12979C>G p.L4327V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV54433884; called by muse, mutect2, varscan2
- DOCK3 | c.4130G>T p.G1377V | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV56515658; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 24/121 reads (20%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DPAGT1 | c.698del p.F233Sfs*28 | Frame Shift Del (DEL) | VAF 68/202 reads (34%) | catalogued as rs35482889; called by mutect2, varscan2
- DSG2 | c.2572G>A p.A858T | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV55198421; called by muse, mutect2, varscan2
- DST | c.4496del p.L1499Wfs*8 (on ENST00000361203 / NM_001374722.1; = p.L1173Wfs*8 on NM_015548.5) | Frame Shift Del (DEL) | VAF 82/286 reads (29%) | catalogued as rs35805169; called by mutect2, varscan2
- E2F7 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754738203, COSV59738194; called by muse, mutect2, varscan2
- EBF2 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV68777137; called by muse, mutect2
- EEF1AKNMT | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 10/343 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs1243125495, COSV62282877; called by muse, mutect2
- EEF1E1 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 51/215 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65675476; called by muse, mutect2, varscan2
- EFNB1 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0.434); catalogued as COSV52661470; called by muse, mutect2, varscan2
- EGF | c.1885C>T p.Q629* | Nonsense Mutation (SNP) | VAF 52/176 reads (30%) | catalogued as COSV54477751; called by muse, mutect2, varscan2
- EGFLAM | c.2515C>T p.Q839* (on ENST00000354891 / NM_001205301.2; = p.Q831* on NM_152403.4) | Nonsense Mutation (SNP) | VAF 12/178 reads (7%) | catalogued as COSV59298861; called by muse, mutect2
- ELOA | c.1504-1G>T p.X502_splice | Splice Site (SNP) | VAF 73/182 reads (40%) | catalogued as COSV69309989; called by muse, mutect2, varscan2
- ENPP2 | c.1808C>T p.A603V (on ENST00000075322 / NM_001040092.3; = p.A655V on NM_006209.5) | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.667); catalogued as COSV50013186; called by muse, mutect2, varscan2
- EP400 | c.4351C>T p.R1451W | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs145797704; called by muse, mutect2, varscan2
- EPHB1 | c.1519C>T p.R507C | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV67656911, COSV67657380; called by muse, mutect2, varscan2
- EPHB2 | c.466G>A p.V156I | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.031); catalogued as rs376990288; called by muse, mutect2, varscan2
- EPN2 | c.224A>G p.Y75C | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59060848; called by muse, mutect2, varscan2
- EPYC | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.83); PolyPhen benign (0.036); catalogued as COSV53799403; called by muse, varscan2
- ERBB3 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as rs755202592, COSV57250953; called by muse, mutect2, varscan2
- FAT2 | c.12385G>A p.V4129I | Missense Mutation (SNP) | VAF 17/215 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs1162708250, COSV55817849; called by muse, mutect2
- FAT2 | c.9290C>T p.A3097V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV55817862; called by muse, mutect2, varscan2
- FAT3 | c.6190C>T p.R2064C | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs759701930, COSV53099657; called by muse, mutect2, varscan2
- FBXO42 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 14/199 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs376029455; called by muse, mutect2
- FBXO46 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as COSV58348380; called by muse, mutect2
- FFAR2 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.025); catalogued as rs763496041, COSV55832121; called by muse, mutect2, varscan2
- FIGNL1 | c.1955G>A p.R652Q | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs370362313, COSV63553501; called by muse, mutect2, varscan2
- FNIP2 | c.1743del p.I582Sfs*94 | Frame Shift Del (DEL) | VAF 24/88 reads (27%) | catalogued as COSV52437011; called by mutect2, pindel, varscan2
- FOXN3 | c.287del p.P96Hfs*42 | Frame Shift Del (DEL) | VAF 6/63 reads (10%) | catalogued as rs760347049; called by mutect2, pindel
- FRK | c.842T>C p.M281T | Missense Mutation (SNP) | VAF 55/243 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV73383943; called by muse, mutect2, varscan2
- FRMD4A | c.1243C>T p.R415* | Nonsense Mutation (SNP) | VAF 61/168 reads (36%) | catalogued as COSV52720286; called by muse, mutect2, varscan2
- FRMD4A | c.893A>G p.Y298C | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768604155, COSV52720306; called by muse, mutect2, varscan2
- G3BP2 | c.1087A>G p.N363D | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV62976059; called by muse, mutect2, varscan2
- GALNS | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.794); catalogued as CM042055, COSV51936727; called by muse, mutect2, varscan2
- GBP5 | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 74/208 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1449121812, COSV58591331; called by muse, mutect2, varscan2
- GFI1B | c.961C>T p.R321W | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765068455, COSV59743963; called by muse, mutect2, varscan2
- GGA3 | c.641G>A p.R214H (on ENST00000537686 / NM_138619.4; = p.R181H on NM_014001.5) | Missense Mutation (SNP) | VAF 83/223 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs767843294, COSV55456121; called by muse, mutect2, varscan2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 30/49 reads (61%) | catalogued as rs749150409; called by mutect2, varscan2
- GMPS | c.540A>T p.E180D | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV55808956; called by muse, mutect2, varscan2
- GNAZ | c.179G>A p.G60D | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV50737645; called by muse, mutect2, varscan2
- GPATCH8 | c.1513A>G p.T505A | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV59194268; called by muse, mutect2, varscan2
- GPR119 | c.619G>T p.A207S | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.159); catalogued as COSV52275478; called by muse, mutect2, varscan2
- H3-3A | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 67/195 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV64732514; called by muse, mutect2, varscan2
- HAX1 | c.521C>A p.P174H | Missense Mutation (SNP) | VAF 119/332 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); catalogued as rs1257711613, COSV55171261; called by muse, mutect2, varscan2
- HCN3 | c.361_363del p.E121del | In Frame Del (DEL) | VAF 24/102 reads (24%) | catalogued as rs774853370; called by pindel, varscan2
- HDAC4 | c.503G>A p.S168N | Missense Mutation (SNP) | VAF 66/171 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100612699, COSV61863425; called by muse, mutect2, varscan2
- HECTD4 | c.12913G>T p.G4305W | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV66390296; called by muse, varscan2
- HELZ2 | c.4643C>T p.T1548M (on ENST00000467148 / NM_001037335.2; = p.T979M on NM_033405.3) | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.11); PolyPhen benign (0.075); catalogued as rs748645755, COSV71295752; called by muse, mutect2, varscan2
- HLX | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs920741102, COSV65044673; called by muse, mutect2, varscan2
- HMGCR | c.1807G>A p.A603T | Missense Mutation (SNP) | VAF 78/203 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); catalogued as COSV55315259; called by muse, mutect2, varscan2
- HOXB13 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.253); catalogued as COSV51705778; called by muse, mutect2, varscan2
- HSPG2 | c.5351G>A p.R1784H | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs374922688; called by muse, mutect2, varscan2
- HTR3C | c.256A>G p.T86A | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV59175003, COSV59175288; called by muse, mutect2, varscan2
- ID1 | c.313C>T p.L105F | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65888452; called by muse, mutect2, varscan2
- IL16 | c.215G>A p.S72N | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV57262481; called by muse, mutect2
- IL17F | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142962486; called by muse, mutect2, varscan2
- IL3RA | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 109/280 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.934); catalogued as rs773005678, COSV58429897; called by muse, mutect2, varscan2
- IL9R | c.696G>T p.E232D | Missense Mutation (SNP) | VAF 73/253 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV54899088; called by muse, mutect2, varscan2
- INPP4A | c.214G>A p.V72I | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.229); catalogued as COSV50789055; called by muse, mutect2, varscan2
- INSRR | c.3285G>T p.M1095I | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV63872350; called by muse, mutect2, varscan2
- INSRR | c.1045C>T p.H349Y | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.391); catalogued as COSV63872359; called by muse, mutect2, varscan2
- INTS6L | c.359del p.L120* | Frame Shift Del (DEL) | VAF 64/150 reads (43%) | catalogued as rs782242788; ClinVar: uncertain significance; called by mutect2, varscan2
- IPO4 | c.2849C>T p.A950V | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.31); catalogued as rs770452240, COSV61016277; called by muse, mutect2, varscan2
- IPO4 | c.2527G>A p.A843T | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV61016284; called by muse, mutect2
- IRAK4 | c.694C>T p.Q232* | Nonsense Mutation (SNP) | VAF 95/257 reads (37%) | catalogued as COSV71210383; called by muse, mutect2, varscan2
- ISLR2 | c.1976C>T p.P659L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as COSV62301952; called by muse, mutect2, varscan2
- ITGA5 | c.693C>T p.G231= | Splice Region (SNP) | VAF 38/127 reads (30%) | catalogued as COSV53217146; called by muse, mutect2, varscan2
- ITPR2 | c.6319A>G p.N2107D | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749413062, COSV67267977; called by muse, varscan2
- JAM2 | c.65G>C p.G22A | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100468375, COSV57256963; called by muse, mutect2, varscan2
- JAM2 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV57256972; called by muse, mutect2, varscan2
- JMY | c.1621C>T p.Q541* | Nonsense Mutation (SNP) | VAF 53/165 reads (32%) | catalogued as COSV68660610; called by muse, mutect2, varscan2
- KANSL1 | c.3049A>G p.T1017A (on ENST00000574590 / NM_001193465.2; = p.T1018A on NM_015443.4) | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV52239308; called by muse, mutect2, varscan2
- KBTBD6 | c.1326dup p.R443Afs*8 | Frame Shift Ins (INS) | VAF 12/69 reads (17%) | catalogued as rs774820321; called by mutect2, varscan2
- KCNV1 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52085699; called by muse, mutect2, varscan2
- KDM4C | c.1602C>A p.S534R | Missense Mutation (SNP) | VAF 59/162 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as COSV67185759; called by muse, mutect2, varscan2
- KDM5A | c.3597del p.G1200Dfs*9 | Frame Shift Del (DEL) | VAF 62/163 reads (38%) | catalogued as rs771545848; called by mutect2, varscan2
- KHK | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.127); catalogued as rs377146926; called by muse, mutect2, varscan2
- KIAA1549 | c.4912G>A p.A1638T | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54311647; called by muse, mutect2, varscan2
- KIF1A | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57483567; called by muse, mutect2, varscan2
- KIF23 | c.2822C>T p.A941V (on ENST00000260363; = p.A837V on NM_004856.7) | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV52979071; called by muse, mutect2, varscan2
- KIF24 | c.3119C>T p.T1040M | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs757363593, COSV52658520; called by muse, mutect2, varscan2
- KIF4A | c.607A>G p.T203A | Missense Mutation (SNP) | VAF 11/227 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV65542704; called by muse, mutect2
- KLF6 | c.754C>T p.R252* | Nonsense Mutation (SNP) | VAF 9/203 reads (4%) | catalogued as COSV51494344; called by muse, mutect2
- KMT2D | c.16300G>A p.E5434K | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56429894; called by muse, mutect2, varscan2
- KMT5A | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 53/218 reads (24%) | catalogued as COSV57862838; called by muse, mutect2, varscan2
- KRTAP10-1 | c.419C>A p.S140Y | Missense Mutation (SNP) | VAF 65/169 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.108); catalogued as rs782810142, COSV59958751; called by muse, mutect2, varscan2
- LAMA4 | c.2438C>T p.A813V (on ENST00000230538 / NM_001105206.3; = p.A806V on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as COSV57895464; called by muse, mutect2, varscan2
- LAMP2 | c.63G>A p.L21= | Splice Region (SNP) | VAF 14/32 reads (44%) | catalogued as COSV52352546; called by muse, mutect2, varscan2
- LAS1L | c.653T>A p.V218D | Missense Mutation (SNP) | VAF 47/438 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as COSV56706974; called by muse, mutect2, varscan2
- LENG1 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV55362251; called by muse, mutect2, varscan2
- LGALS3BP | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759471172, COSV53164712; called by muse, mutect2, varscan2
- LRP1 | c.10660C>T p.Q3554* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV54508194; called by muse, mutect2
- LRP1 | c.11194+1G>A p.X3732_splice | Splice Site (SNP) | VAF 38/121 reads (31%) | catalogued as rs113296158, COSV54508221; called by muse, mutect2, varscan2
- LRP1 | c.11990C>T p.S3997L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as rs908851844, COSV54508232; called by muse, mutect2, varscan2
- LRP1B | c.7568G>A p.C2523Y | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67207421; called by muse, mutect2, varscan2
- LRP8 | c.1293G>T p.E431D | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as COSV60097781; called by muse, mutect2, varscan2
- LRRC14 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52878919; called by muse, mutect2, varscan2
- LRRC59 | c.115C>A p.P39T | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.176); catalogued as COSV56814276; called by muse, mutect2
- LRRIQ3 | c.424C>T p.H142Y | Missense Mutation (SNP) | VAF 70/214 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV63040761; called by muse, mutect2, varscan2
- LRRN2 | c.1711G>A p.A571T | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.085); catalogued as COSV65783561; called by muse, mutect2, varscan2
- LTBP2 | c.1756del p.V586* | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | catalogued as rs776807257; called by mutect2, pindel, varscan2
- LUZP4 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.81); catalogued as rs782634132, COSV64218529; called by muse, mutect2, varscan2
- LYST | c.11093A>G p.H3698R | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.281); catalogued as COSV67706120; called by muse, mutect2, varscan2
- LYZL4 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs886913036, COSV55103923; called by muse, mutect2, varscan2
- LZIC | c.511C>A p.L171I | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as COSV65890313; called by muse, mutect2, varscan2
- LZTR1 | c.2090G>A p.R697Q | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370638947, COSV53146780; called by muse, mutect2, varscan2
- MAB21L2 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58261533; called by muse, mutect2, varscan2
- MACF1 | c.5339T>C p.I1780T | Missense Mutation (SNP) | VAF 36/106 reads (34%) | catalogued as COSV57117515; called by muse, mutect2, varscan2
- MAGED1 | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); catalogued as rs374985036, COSV58515031; called by muse, mutect2, varscan2
- MAP3K15 | c.3622A>G p.T1208A | Missense Mutation (SNP) | VAF 22/311 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58828586; called by muse, mutect2
- MAP3K3 | c.1268G>A p.R423H | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs1219703682, COSV51991637; called by muse, mutect2, varscan2
- MAPK7 | c.1544G>T p.R515L | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV55190062, COSV55191980; called by muse, mutect2, varscan2
- MATN4 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 14/86 reads (16%) | PolyPhen benign (0.001); catalogued as rs866500348, COSV59213326; called by muse, mutect2, varscan2
- MBD6 | c.2200del p.Q734Nfs*18 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs749738168; called by mutect2, pindel, varscan2
- MDH2 | c.129_131del p.L44del | In Frame Del (DEL) | VAF 27/77 reads (35%) | catalogued as rs1242534362; called by mutect2, pindel, varscan2
- MED13 | c.2175del p.K725Nfs*4 | Frame Shift Del (DEL) | VAF 111/395 reads (28%) | catalogued as COSV67261860; called by mutect2, pindel, varscan2
- MED13L | c.821-1G>T p.X274_splice | Splice Site (SNP) | VAF 33/100 reads (33%) | catalogued as COSV56118659; called by muse, mutect2, varscan2
- MED15 | c.1771G>A p.A591T (on ENST00000263205 / NM_001003891.3; = p.A551T on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV53028658; called by muse, mutect2, varscan2
- MEGF10 | c.2087G>T p.G696V | Missense Mutation (SNP) | VAF 9/179 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57248082; called by muse, mutect2
- MEX3B | c.962dup p.S322* | Frame Shift Ins (INS) | VAF 8/20 reads (40%) | catalogued as rs745465397; called by mutect2, varscan2
- MFRP | c.181C>T p.Q61* (on ENST00000449574; = p.Q437* on NM_031433.4) | Nonsense Mutation (SNP) | VAF 24/72 reads (33%) | catalogued as COSV64128240; called by muse, mutect2, varscan2
- MGAM | c.3976C>T p.Q1326* | Nonsense Mutation (SNP) | VAF 33/129 reads (26%) | catalogued as COSV72074461; called by muse, mutect2, varscan2
- MGAT5B | c.2062G>A p.A688T (on ENST00000569840 / NM_001199172.2; = p.A686T on NM_144677.3) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs367906821; called by muse, mutect2, varscan2
- MIDEAS | c.2389G>A p.E797K | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV54094171; called by muse, mutect2, varscan2
- MIGA2 | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.95); catalogued as COSV52976558; called by muse, mutect2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 29/78 reads (37%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MINK1 | c.1121A>T p.Q374L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (1); PolyPhen possibly damaging (0.775); catalogued as rs960631062, COSV61789681; called by muse, mutect2, varscan2
- MINPP1 | c.687dup p.D230* | Frame Shift Ins (INS) | VAF 35/87 reads (40%) | catalogued as rs1249046608; called by mutect2, pindel, varscan2
- MMS19 | c.1466T>G p.L489R | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59134837; called by muse, mutect2, varscan2
- MNDA | c.239A>G p.N80S | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.129); catalogued as rs1338585596, COSV63740556; called by muse, mutect2, varscan2
- MRPS30 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs368376102; called by muse, mutect2
- MSH3 | c.2090G>T p.G697V | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54150084; called by muse, mutect2
- MSH4 | c.461del p.P154Hfs*5 | Frame Shift Del (DEL) | VAF 31/157 reads (20%) | catalogued as COSV54203955; called by mutect2, pindel, varscan2
- MSMO1 | c.804G>T p.W268C | Missense Mutation (SNP) | VAF 60/183 reads (33%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV54970090; called by muse, mutect2, varscan2
- MST1R | c.3396del p.L1133Cfs*6 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | catalogued as COSV56565222; called by mutect2, pindel, varscan2
- MSX1 | c.653T>A p.I218K | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66946967; called by muse, varscan2
- MTAP | c.618G>T p.K206N | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.215); catalogued as COSV66477350; called by muse, mutect2, varscan2
- MTBP | c.1453C>T p.R485* | Nonsense Mutation (SNP) | VAF 33/113 reads (29%) | catalogued as rs778984070, COSV59962288; called by muse, varscan2
- MTF2 | c.1188del p.G397Efs*6 | Frame Shift Del (DEL) | VAF 26/101 reads (26%) | catalogued as rs759847587; called by mutect2, varscan2
- MTMR11 | c.684-1G>A p.X228_splice (on ENST00000439741 / NM_001145862.2; = p.X156_splice on NM_181873.3) | Splice Site (SNP) | VAF 5/99 reads (5%) | catalogued as COSV63805569; called by muse, mutect2
- MTPAP | c.902G>A p.G301D | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV53932440; called by muse, mutect2, varscan2
- MUC16 | c.41164C>G p.Q13722E | Missense Mutation (SNP) | VAF 60/193 reads (31%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.535); catalogued as COSV66691258; called by muse, mutect2, varscan2
- MUC16 | c.7520G>A p.S2507N | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.682); catalogued as COSV67460067; called by muse, mutect2
- MUC4 | c.14233A>C p.S4745R (on ENST00000463781 / NM_018406.7; = p.S509R on NM_004532.6) | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); catalogued as COSV57776586; called by muse, mutect2, varscan2
- MUC5B | c.1100dup p.G368Rfs*6 | Frame Shift Ins (INS) | VAF 7/22 reads (32%) | catalogued as rs1403353463; called by mutect2, pindel, varscan2
- MUC5B | c.6470C>A p.P2157H | Missense Mutation (SNP) | VAF 119/227 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.429); catalogued as rs763540271, COSV71591372; called by muse, mutect2, varscan2
- MUCL3 | c.1249G>T p.G417* (on ENST00000304311; = p.G1293* on NM_080870.4) | Nonsense Mutation (SNP) | VAF 6/105 reads (6%) | catalogued as COSV58516932; called by muse, mutect2
- MYH3 | c.4879G>A p.E1627K | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV56861514; called by muse, mutect2
- MYO7A | c.1606G>A p.A536T | Missense Mutation (SNP) | VAF 119/353 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs201046979; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- NAA25 | c.477+2T>A p.X159_splice | Splice Site (SNP) | VAF 51/167 reads (31%) | catalogued as COSV55703729; called by muse, mutect2, varscan2
- NAALAD2 | c.1415C>T p.P472L | Missense Mutation (SNP) | VAF 87/278 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as COSV58960246; called by muse, mutect2, varscan2
- NAT10 | c.188T>C p.L63P | Missense Mutation (SNP) | VAF 26/380 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV57663236; called by muse, mutect2
- NCAPG2 | c.1610G>A p.C537Y | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51986846; called by muse, mutect2
- NDUFC2 | c.207del p.F69Lfs*7 | Frame Shift Del (DEL) | VAF 42/134 reads (31%) | catalogued as rs747914168; called by mutect2, varscan2
- NEB | c.7946T>C p.L2649P | Missense Mutation (SNP) | VAF 59/154 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51113946; called by muse, mutect2, varscan2
- NEB | c.1811del p.N604Tfs*5 | Frame Shift Del (DEL) | VAF 119/431 reads (28%) | catalogued as COSV51011633, COSV51130501; called by mutect2, pindel, varscan2
- NFASC | c.143C>T p.A48V (on ENST00000339876 / NM_001378329.1; = p.A42V on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs766864514, COSV100362752, COSV58363732; called by muse, mutect2, varscan2
- NHS | c.2842G>A p.A948T | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762685365, COSV66271110; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NHSL2 | c.1609G>A p.A537T (on ENST00000510661; = p.A903T on NM_001013627.2) | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV65453105; called by muse, mutect2
- NIPAL4 | c.478G>A p.G160S | Missense Mutation (SNP) | VAF 167/493 reads (34%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.879); catalogued as rs756409733, COSV61729762; called by muse, mutect2, varscan2
- NOSIP | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs1186539310, COSV59198586; called by muse, mutect2, varscan2
- NOVA2 | c.379C>A p.P127T | Missense Mutation (SNP) | VAF 107/328 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.537); catalogued as COSV54356904; called by muse, mutect2, varscan2
- NPRL3 | c.824C>A p.P275H (on ENST00000611875 / NM_001077350.3; = p.P250H on NM_001039476.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV67852714; called by mutect2, varscan2
- NPTX2 | c.637G>T p.E213* | Nonsense Mutation (SNP) | VAF 9/24 reads (38%) | catalogued as COSV55716870; called by muse, mutect2, varscan2
- NR3C2 | c.338G>A p.R113K | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.621); catalogued as COSV60988849; called by muse, mutect2
- NSD3 | c.3929G>A p.R1310Q | Missense Mutation (SNP) | VAF 22/390 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs758159008, COSV57668593; called by muse, mutect2
- NT5DC2 | c.1302-1G>T p.X434_splice | Splice Site (SNP) | VAF 12/34 reads (35%) | catalogued as COSV58734948; called by muse, mutect2, varscan2
- NYAP2 | c.1765G>A p.V589I | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.291); catalogued as COSV56003108; called by muse, mutect2, varscan2
- OGDH | c.1165A>G p.K389E | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV56048447; called by muse, mutect2, varscan2
- OGFOD3 | c.543C>T p.Y181= | Splice Region (SNP) | VAF 7/68 reads (10%) | catalogued as COSV57340153; called by muse, mutect2
- OLFM4 | c.962T>C p.L321S | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV54576819; called by muse, varscan2
- OR14C36 | c.315dup p.V106Cfs*14 | Frame Shift Ins (INS) | VAF 16/72 reads (22%) | catalogued as rs761899382; called by mutect2, varscan2
- OR2A7 | c.532del p.C178Vfs*37 | Frame Shift Del (DEL) | VAF 23/186 reads (12%) | catalogued as rs749245232; called by mutect2, pindel, varscan2
- OR2F2 | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 83/289 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs371292578, COSV101283812; called by muse, mutect2, varscan2
- OR2G2 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 103/259 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV60740206; called by muse, mutect2, varscan2
- OR56B4 | c.866del p.P289Lfs*42 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs753608211, COSV57205734; called by mutect2, pindel, varscan2
- OR5H14 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 47/194 reads (24%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.703); catalogued as COSV71193821; called by muse, mutect2, varscan2
- PAF1 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 76/219 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs751010774, COSV55393484; called by muse, mutect2, varscan2
- PAK1 | c.772C>T p.R258* | Nonsense Mutation (SNP) | VAF 110/341 reads (32%) | catalogued as rs201726311, COSV53695751; called by muse, mutect2, varscan2
- PALB2 | c.1637T>C p.V546A | Missense Mutation (SNP) | VAF 75/254 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as rs148647206; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PAPLN | c.1514G>A p.R505Q (on ENST00000554301; = p.R478Q on NM_173462.4) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs189127558, COSV53716438; called by muse, mutect2, varscan2
- PARD3 | c.1492dup p.A498Gfs*9 | Frame Shift Ins (INS) | VAF 21/103 reads (20%) | catalogued as rs781028175; called by mutect2, pindel, varscan2
- PARD3 | c.1018G>A p.A340T | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV60748358; called by muse, mutect2, varscan2
- PAXIP1 | c.2391G>T p.Q797H | Missense Mutation (SNP) | VAF 33/191 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as COSV68185661; called by muse, mutect2, varscan2
- PAXIP1 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.977); catalogued as rs760584538, COSV101249767, COSV68185672; called by muse, mutect2, varscan2
- PBX3 | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 80/209 reads (38%) | catalogued as COSV60730272; called by muse, mutect2, varscan2
- PCCB | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 11/244 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as COSV52444606; called by muse, mutect2
- PCDH10 | c.2161G>A p.A721T | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as rs1560703933, COSV52090820; called by muse, mutect2, varscan2
- PCDH15 | c.5052G>T p.E1684D | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT tolerated, low confidence (0.09); catalogued as COSV64671826, COSV64688036; called by muse, mutect2, varscan2
- PCDH15 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 85/246 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV57293714; called by muse, mutect2
- PCDHA1 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.397); catalogued as rs782726332, COSV65373571; called by muse, mutect2, varscan2
- PCDHA12 | c.1306T>C p.W436R | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.155); catalogued as rs782434844, COSV56493850; called by muse, mutect2, varscan2
- PCDHA12 | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.06); catalogued as rs560974692, COSV56482468; called by muse, mutect2, varscan2
- PCDHA3 | c.790G>A p.V264I | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.417); catalogued as COSV65366290; called by muse, mutect2
- PCDHA7 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65343512; called by muse, mutect2
- PCDHA8 | c.1690G>A p.A564T | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as rs1554139637, COSV65325485; called by muse, mutect2, varscan2
- PCDHGB4 | c.503A>G p.Q168R | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs746929136, COSV53930649; called by muse, mutect2, varscan2
- PCDHGB4 | c.1570C>T p.R524C | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs544789937, COSV53910620; called by muse, mutect2, varscan2
- PCDHGC5 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs200464357, COSV52749274; called by muse, mutect2, varscan2
- PCMTD1 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.02); catalogued as rs767756923, COSV62119286; called by muse, mutect2, varscan2
- PCNT | c.8642G>A p.R2881Q | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as rs753972547, COSV64027182; called by muse, mutect2, varscan2
- PDE2A | c.17G>A p.G6D | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV57805322; called by muse, mutect2, varscan2
- PDGFRB | c.2819G>A p.C940Y | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757873895, COSV55803676; called by muse, mutect2, varscan2
- PDLIM7 | c.572+2T>C p.X191_splice | Splice Site (SNP) | VAF 24/62 reads (39%) | catalogued as COSV62883189; called by muse, mutect2, varscan2
- PDPR | c.101del p.A34Gfs*56 | Frame Shift Del (DEL) | VAF 25/86 reads (29%) | catalogued as COSV55350937; called by pindel, varscan2
- PHC3 | c.2239G>A p.V747I (on ENST00000494943 / NM_001308116.2; = p.V759I on NM_024947.4) | Missense Mutation (SNP) | VAF 76/291 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.775); catalogued as COSV71948585; called by muse, mutect2, varscan2
- PI4KB | c.1193T>C p.L398P (on ENST00000368873 / NM_001369623.1; = p.L410P on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV55016734; called by muse, mutect2, varscan2
- PIGB | c.840del p.F280Lfs*12 | Frame Shift Del (DEL) | VAF 143/400 reads (36%) | catalogued as rs756552559; called by mutect2, varscan2
- PIGW | c.131A>G p.Q44R | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.178); catalogued as rs1409685480; called by muse, mutect2
- PIK3C2B | c.859dup p.R287Pfs*38 | Frame Shift Ins (INS) | VAF 16/52 reads (31%) | catalogued as rs749506841; called by mutect2, varscan2
- PKD2L2 | c.910del p.I304* | Frame Shift Del (DEL) | VAF 114/340 reads (34%) | catalogued as rs758905083; called by mutect2, pindel, varscan2
- PLEC | c.12783G>T p.K4261N (on ENST00000322810 / NM_201380.4; = p.K4151N on NM_000445.5) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV59626170; called by muse, mutect2, varscan2
- PLEKHA4 | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); catalogued as rs770347579, COSV54362488; called by muse, mutect2, varscan2
- PLEKHM1 | c.1816C>T p.R606C | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760295037, COSV69598463; called by mutect2, varscan2
- PLK4 | c.691C>A p.P231T | Missense Mutation (SNP) | VAF 12/221 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54636525, COSV54637171; called by muse, mutect2
- PLTP | c.1143del p.K382Rfs*26 | Frame Shift Del (DEL) | VAF 6/11 reads (55%) | catalogued as rs1328884536; called by mutect2, varscan2
- PLXNA1 | c.1552T>C p.Y518H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as COSV52525021; called by muse, mutect2, varscan2
- PLXNA1 | c.3946G>A p.G1316S | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.931); catalogued as rs750147010, COSV52525033; called by muse, mutect2, varscan2
- PMS2 | c.1239del p.D414Tfs*34 | Frame Shift Del (DEL) | VAF 28/72 reads (39%) | catalogued as CD040607; called by mutect2, varscan2
- PNMA1 | c.248G>A p.G83D | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54094159; called by muse, mutect2, varscan2
- PORCN | c.20A>G p.Q7R | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV58225995; called by muse, mutect2, varscan2
- POU2F1 | c.333+1G>C p.X111_splice (on ENST00000541643 / NM_001365848.1; = p.X134_splice on NM_002697.4) | Splice Site (SNP) | VAF 21/85 reads (25%) | catalogued as COSV54815514; called by muse, mutect2, varscan2
- PPP1R3A | c.1711G>A p.A571T | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765161960, COSV52877395, COSV52890078; called by muse, mutect2, varscan2
- PPP2R3B | c.332C>T p.T111I | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV66813108; called by muse, mutect2, varscan2
- PPWD1 | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 103/272 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs199936033, COSV54333381; called by muse, mutect2, varscan2
- PRDM2 | c.168del p.F56Lfs*47 | Frame Shift Del (DEL) | VAF 42/198 reads (21%) | catalogued as COSV99340511; called by mutect2, pindel, varscan2
- PRKACG | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV55245418; called by muse, mutect2, varscan2
- PROSER3 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.056); catalogued as COSV56553186; called by muse, mutect2, varscan2
- PROZ | c.573G>T p.Q191H | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61439197; called by muse, mutect2, varscan2
- PTCH2 | c.3505del p.L1169Cfs*85 | Frame Shift Del (DEL) | VAF 21/52 reads (40%) | catalogued as rs763413121; called by mutect2, pindel, varscan2
- PTEN | c.220del p.R74Dfs*25 | Frame Shift Del (DEL) | VAF 57/121 reads (47%) | catalogued as COSV64310876; called by mutect2, pindel, varscan2
- PTPN11 | c.1664G>A p.G555E | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.083); catalogued as COSV61008072; called by muse, mutect2, varscan2
- PTPRD | c.769T>C p.C257R | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61938909, COSV61976040; called by muse, mutect2, varscan2
- PTPRU | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV60523095; called by muse, mutect2, varscan2
- PURG | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.37); catalogued as COSV53298935; called by muse, mutect2, varscan2
- PXDN | c.4060C>T p.R1354W | Missense Mutation (SNP) | VAF 79/225 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as rs565398993, COSV53230056; called by muse, mutect2, varscan2
- PXN | c.1646C>T p.A549V (on ENST00000228307 / NM_001080855.3; = p.A515V on NM_002859.4) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57218241; called by muse, mutect2, varscan2
- PYGO1 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as rs564470411, COSV57347357; called by muse, mutect2, varscan2
- RAB2A | c.455C>G p.T152S | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.124); catalogued as COSV52911053; called by muse, mutect2, varscan2
- RANBP3 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50380774; called by muse, mutect2, varscan2
- RASD2 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs921592856, COSV53352354; called by muse, mutect2, varscan2
- RBM10 | c.1352_1353del p.E451Vfs*66 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as rs1131690789; called by pindel, varscan2
- RBM10 | c.1905G>T p.E635D | Missense Mutation (SNP) | VAF 8/201 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.056); catalogued as COSV61308668; called by muse, mutect2
- RBM12B | c.1018G>A p.A340T | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1050119972, COSV66968091; called by muse, mutect2, varscan2
- RFTN1 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs764801487, COSV61918261; called by muse, mutect2, varscan2
- RHOBTB2 | c.899T>C p.L300P | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV52570558; called by muse, mutect2, varscan2
- RIMS2 | c.905G>A p.R302K (on ENST00000666250 / NM_001348490.2; = p.R110K on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT tolerated (1); PolyPhen possibly damaging (0.542); catalogued as COSV51672500; called by muse, mutect2, varscan2
- RIPK4 | c.1636A>G p.N546D (on ENST00000352483; = p.N498D on NM_020639.3) | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60186769; called by muse, mutect2, varscan2
- RMND1 | c.1205T>C p.M402T | Missense Mutation (SNP) | VAF 66/205 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV60550409; called by muse, mutect2, varscan2
- RNASE2 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as COSV58941096; called by muse, mutect2, varscan2
- RNF128 | c.31del p.W11Gfs*4 | Frame Shift Del (DEL) | VAF 52/160 reads (33%) | catalogued as rs757038390; called by mutect2, varscan2
- RNF26 | c.533G>A p.W178* | Nonsense Mutation (SNP) | VAF 36/92 reads (39%) | catalogued as rs1193278956, COSV60990234; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 36/63 reads (57%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RRM2B | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV52566450; called by muse, mutect2
- RSAD1 | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.95); catalogued as rs747181180, COSV51955335, COSV51956718; called by muse, mutect2, varscan2
- RTL8B | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1237774082, COSV66954235, COSV66954360; called by muse, mutect2, varscan2
- RTN3 | c.3089del p.K1030Rfs*67 (on ENST00000377819 / NM_001265589.2; = p.K234Rfs*67 on NM_006054.4) | Frame Shift Del (DEL) | VAF 62/170 reads (36%) | catalogued as rs747510098; called by mutect2, varscan2
- RUFY2 | c.314C>T p.T105I | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs758682535, COSV61190939; called by muse, mutect2
- RUSC2 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs201053580, COSV63428373; called by muse, mutect2, varscan2
- RYR3 | c.1024G>T p.G342* | Nonsense Mutation (SNP) | VAF 37/171 reads (22%) | catalogued as COSV66785128; called by muse, mutect2, varscan2
- RYR3 | c.7717C>T p.P2573S (on ENST00000389232; = p.P2574S on NM_001036.6) | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.873); catalogued as COSV66785132; called by muse, mutect2
- SAGE1 | c.521T>G p.V174G | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV61012728; called by muse, mutect2
- SALL3 | c.3647C>T p.A1216V | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV73305961; called by muse, mutect2, varscan2
- SCAP | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.701); catalogued as rs745402503, COSV55559168; called by muse, mutect2, varscan2
- SCNM1 | c.502C>A p.P168T | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV54860211; called by muse, mutect2, varscan2
- SCUBE2 | c.1692C>A p.S564R | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV58542077; called by muse, mutect2, varscan2
- SDF4 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV55418477; called by muse, mutect2, varscan2
- SEC16A | c.6197del p.P2066Qfs*76 | Frame Shift Del (DEL) | VAF 8/45 reads (18%) | catalogued as COSV99256980; called by mutect2, pindel
- SEC31B | c.2746C>T p.P916S | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs368613786, COSV64844176; called by muse, mutect2, varscan2
- SERPINE1 | c.486G>T p.W162C | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56169284; called by muse, mutect2, varscan2
- SGPL1 | c.1580G>A p.G527D | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64591414; called by muse, mutect2, varscan2
- SHANK2 | c.4243_4244insA p.L1415Hfs*6 | Frame Shift Ins (INS) | VAF 21/97 reads (22%) | catalogued as COSV99574820; called by mutect2, pindel, varscan2
- SHCBP1 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57647223; called by muse, mutect2, varscan2
- SHROOM2 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV66605849; called by muse, mutect2, varscan2
- SIGLEC10 | c.926A>G p.E309G | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV59480902; called by muse, mutect2, varscan2
- SIGLEC6 | c.38T>A p.L13Q | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.657); catalogued as COSV58433382; called by muse, mutect2, varscan2
- SIN3A | c.974A>G p.Y325C | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760260844, COSV64582527; called by muse, mutect2, varscan2
- SLC17A2 | c.361dup p.M121Nfs*21 | Frame Shift Ins (INS) | VAF 66/226 reads (29%) | catalogued as rs770669846; called by mutect2, varscan2
- SLC25A39 | c.994C>A p.P332T (on ENST00000377095 / NM_001143780.3; = p.P324T on NM_016016.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56587000; called by muse, mutect2, varscan2
- SLC2A11 | c.347G>A p.R116H (on ENST00000345044 / NM_001024938.4; = p.R123H on NM_030807.5) | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as rs768582330, COSV55390958; called by muse, mutect2, varscan2
- SLX4 | c.1406dup p.L470Ifs*8 | Frame Shift Ins (INS) | VAF 12/46 reads (26%) | catalogued as rs774532876; called by mutect2, varscan2
- SMC3 | c.127del p.Y43Mfs*69 | Frame Shift Del (DEL) | VAF 43/148 reads (29%) | catalogued as rs1466680694; called by mutect2, pindel, varscan2
- SPAG16 | c.422T>C p.V141A | Missense Mutation (SNP) | VAF 72/244 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0.011); catalogued as COSV55984850; called by muse, mutect2, varscan2
- SPAG17 | c.739G>A p.V247M | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762885045, COSV60456915; called by muse, mutect2, varscan2
- SPATA32 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.237); catalogued as COSV59303475; called by muse, varscan2
- SPESP1 | c.602A>G p.Q201R | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV52987578; called by muse, mutect2, varscan2
- SPIC | c.197G>T p.W66L | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54690890; called by muse, mutect2, varscan2
- SPTAN1 | c.3035G>A p.R1012H | Missense Mutation (SNP) | VAF 70/201 reads (35%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.991); catalogued as rs1265382491, COSV63986551; ClinVar: likely benign; called by muse, mutect2, varscan2
- SPTBN4 | c.6269A>G p.H2090R | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58947493; called by muse, mutect2
- SRRM4 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.911); catalogued as rs368516977; called by muse, mutect2
- SSR3 | c.466A>G p.I156V | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs1340645649, COSV54020348; called by muse, mutect2
- ST8SIA6 | c.753del p.A252Pfs*53 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | catalogued as rs758746672, COSV66468613; called by mutect2, varscan2
- STAB1 | c.3364dup p.R1122Pfs*37 | Frame Shift Ins (INS) | VAF 14/51 reads (27%) | catalogued as rs563085224; called by mutect2, varscan2
- STAG2 | c.2219del p.V740Efs*9 | Frame Shift Del (DEL) | VAF 61/215 reads (28%) | catalogued as COSV54356117; called by mutect2, pindel, varscan2
- STAMBPL1 | c.1214del p.K405Rfs*21 | Frame Shift Del (DEL) | VAF 70/127 reads (55%) | catalogued as rs752994755; called by mutect2, varscan2
- STEAP2 | c.680dup p.L228Pfs*14 | Frame Shift Ins (INS) | VAF 79/258 reads (31%) | catalogued as rs754344704; called by mutect2, varscan2
- SV2B | c.1755dup p.G586Wfs*4 | Frame Shift Ins (INS) | VAF 87/236 reads (37%) | catalogued as rs1567438858; called by mutect2, pindel, varscan2
- SVEP1 | c.10354C>A p.L3452M | Missense Mutation (SNP) | VAF 17/209 reads (8%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.9); catalogued as COSV52838224; called by muse, mutect2
- SYBU | c.827T>C p.V276A (on ENST00000276646 / NM_001099754.2; = p.V275A on NM_017786.6) | Missense Mutation (SNP) | VAF 17/262 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52616916; called by muse, mutect2
- TADA3 | c.454A>G p.N152D | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV55028415; called by muse, mutect2, varscan2
- TANC2 | c.4802A>G p.Q1601R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.094); catalogued as COSV67333349; called by muse, mutect2, varscan2
- TBR1 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 89/258 reads (34%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.979); catalogued as rs868472878, COSV67417693; called by muse, mutect2, varscan2
- TCTN2 | c.682G>A p.V228I | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.139); catalogued as rs1195874823, COSV57632491; called by muse, mutect2, varscan2
- TDRD6 | c.5432A>G p.Y1811C | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.747); catalogued as rs796584974, COSV60175089; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 34/76 reads (45%) | catalogued as rs763321097; called by mutect2, varscan2
- TEX13B | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0.036); catalogued as COSV57202522; called by muse, mutect2, varscan2
- TFAP4 | c.71T>C p.V24A | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.857); catalogued as COSV52597358; called by muse, mutect2, varscan2
- TGFBR3 | c.578T>C p.F193S | Missense Mutation (SNP) | VAF 59/206 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.786); catalogued as COSV53024446; called by muse, mutect2, varscan2
- TGFBR3 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 62/248 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs781532156, COSV53024460; called by muse, mutect2, varscan2
- THOC1 | c.1602G>A p.P534= | Splice Region (SNP) | VAF 106/267 reads (40%) | catalogued as rs755407022, COSV55274886; called by muse, mutect2, varscan2
- TIAM2 | c.3605G>A p.S1202N | Missense Mutation (SNP) | VAF 36/381 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51639632; called by muse, mutect2, varscan2
- TIMP3 | c.602dup p.D202Gfs*2 | Frame Shift Ins (INS) | VAF 12/44 reads (27%) | catalogued as rs749890843; called by mutect2, varscan2
- TJP2 | c.2375A>G p.D792G | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55265676; called by muse, mutect2, varscan2
- TLR1 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58304005; called by muse, mutect2, varscan2
- TLR9 | c.437T>C p.I146T | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV59726251; called by muse, mutect2
- TMEM38A | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); catalogued as rs139650677, COSV51818851; called by muse, mutect2, varscan2
- TMEM41A | c.467del p.F156Sfs*5 | Frame Shift Del (DEL) | VAF 46/114 reads (40%) | catalogued as rs758476632; called by mutect2, varscan2
- TMEM8B | c.1300G>T p.G434W | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV65076226; called by muse, mutect2, varscan2
- TMEM97 | c.528del p.K176Nfs*188 | Frame Shift Del (DEL) | VAF 42/144 reads (29%) | catalogued as rs781830688; called by mutect2, varscan2
- TNC | c.5746G>A p.G1916S | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.993); catalogued as rs376093344; called by muse, mutect2, varscan2
- TNRC6B | c.2885G>T p.W962L (on ENST00000454349 / NM_001162501.2; = p.W215L on NM_001024843.1) | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57293438; called by muse, mutect2, varscan2
- TOMM70 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 21/235 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52522962; called by muse, mutect2
- TOP3B | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1451103267, COSV64116972; called by muse, mutect2, varscan2
- TRIM60 | c.969dup p.R324Tfs*6 | Frame Shift Ins (INS) | VAF 51/147 reads (35%) | catalogued as rs745660493; called by mutect2, varscan2
- TRPV3 | c.259del p.Q87Sfs*7 | Frame Shift Del (DEL) | VAF 40/134 reads (30%) | catalogued as rs911130511, COSV100027514; called by mutect2, pindel, varscan2
- TSC2 | c.4292C>T p.S1431L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs375785710, COSV51920651; ClinVar: benign; called by muse, mutect2, varscan2
- TSNARE1 | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56174185; called by muse, mutect2, varscan2
- TSPO | c.460G>A p.V154I | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs771545866, COSV53354842; called by muse, varscan2
- TSPOAP1 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.724); catalogued as rs750610515, COSV52107146; called by muse, mutect2, varscan2
- TSPYL4 | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs201235988, COSV60307841; called by muse, mutect2, varscan2
- TTC13 | c.350A>G p.N117S | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as rs1333008134, COSV64168367; called by muse, mutect2, varscan2
- UBA1 | c.120A>G p.G40= | Splice Region (SNP) | VAF 35/169 reads (21%) | catalogued as COSV60112252; called by muse, mutect2, varscan2
- UBR5 | c.6360del p.E2121Kfs*28 | Frame Shift Del (DEL) | VAF 102/315 reads (32%) | catalogued as rs763652408; called by mutect2, varscan2
- UBR5 | c.1070_1072del p.G357del | In Frame Del (DEL) | VAF 43/183 reads (23%) | catalogued as rs776412815; called by mutect2, pindel, varscan2
- ULK1 | c.158T>C p.L53P | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58855981; called by muse, varscan2
- ULK1 | c.1909C>T p.P637S | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.103); catalogued as rs1026182570, COSV58855984, COSV58857495; called by muse, mutect2
- UNC79 | c.6757C>T p.R2253* (on ENST00000393151 / NM_001346218.2; = p.R2076* on NM_020818.5) | Nonsense Mutation (SNP) | VAF 12/360 reads (3%) | catalogued as COSV56383345; called by muse, mutect2
- UNK | c.1469G>A p.G490D | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV53141015; called by muse, mutect2, varscan2
- USP35 | c.1127T>C p.L376P | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71572711; called by muse, mutect2, varscan2
- UVRAG | c.709del p.S237Vfs*6 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | catalogued as rs762976381; called by mutect2, varscan2
- VCPIP1 | c.976C>T p.L326F | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV60046755; called by muse, mutect2, varscan2
- VPS13B | c.11242G>A p.G3748S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.321); catalogued as COSV62138998; called by muse, mutect2, varscan2
- VPS33A | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs200143325, COSV57355926; called by muse, mutect2, varscan2
- VWA2 | c.1411C>T p.R471* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as rs370405238; called by muse, mutect2, varscan2
- WAS | c.293A>T p.E98V | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64996933; called by muse, mutect2, varscan2
- WDR36 | c.1444G>T p.A482S | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV72411092; called by muse, mutect2, varscan2
- WDR55 | c.1022del p.K341Rfs*8 | Frame Shift Del (DEL) | VAF 20/70 reads (29%) | catalogued as rs746919573; called by mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 38/59 reads (64%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WHAMM | c.2395A>G p.S799G | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV54495997; called by muse, mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs779864368; called by mutect2, varscan2
- YLPM1 | c.3530G>T p.G1177V | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.944); catalogued as COSV53110089; called by muse, mutect2, varscan2
- ZBTB47 | c.1369G>A p.V457M | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs938169734, COSV51764178; called by muse, mutect2, varscan2
- ZFP91 | c.854G>T p.R285M | Missense Mutation (SNP) | VAF 15/337 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV60158385; called by muse, mutect2
- ZKSCAN8 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV57637646; called by muse, mutect2, varscan2
- ZMYM2 | c.3131del p.K1044Rfs*33 | Frame Shift Del (DEL) | VAF 97/301 reads (32%) | catalogued as rs753611080; called by mutect2, varscan2
- ZMYM4 | c.1290del p.K430Nfs*6 | Frame Shift Del (DEL) | VAF 72/216 reads (33%) | catalogued as rs755663477, COSV58913572; called by mutect2, varscan2
- ZMYND8 | c.3275G>A p.S1092N (on ENST00000311275 / NM_001363741.2; = p.S1066N on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/180 reads (21%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV53685891, COSV53688515; called by muse, mutect2, varscan2
- ZMYND8 | c.2796+2T>C p.X932_splice (on ENST00000311275 / NM_001363741.2; = p.X906_splice on NM_012408.6 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 30/95 reads (32%) | catalogued as COSV53685907; called by muse, mutect2, varscan2
- ZNF165 | c.579G>A p.M193I | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV66102311; called by muse, mutect2
- ZNF202 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs747324866, COSV60246906; called by muse, mutect2, varscan2
- ZNF239 | c.223C>T p.Q75* | Nonsense Mutation (SNP) | VAF 75/244 reads (31%) | catalogued as rs1213639926, COSV60018478; called by muse, mutect2, varscan2
- ZNF26 | c.428G>T p.R143I | Missense Mutation (SNP) | VAF 82/222 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs922345868; called by muse, mutect2, varscan2
- ZNF292 | c.1799T>C p.L600P | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60538298; called by muse, mutect2
- ZNF300 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.25); catalogued as rs779596151, COSV51034332; called by muse, mutect2, varscan2
- ZNF407 | c.3173G>A p.R1058H | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs368385934; called by muse, mutect2, varscan2
- ZNF446 | c.628-1G>T p.X210_splice | Splice Site (SNP) | VAF 20/74 reads (27%) | catalogued as COSV59991238; called by muse, mutect2, varscan2
- ZNF718 | c.424del p.T142Qfs*22 | Frame Shift Del (DEL) | VAF 21/99 reads (21%) | catalogued as rs781974194; called by mutect2, pindel, varscan2
- ZNF768 | c.832C>T p.Q278* | Nonsense Mutation (SNP) | VAF 30/73 reads (41%) | catalogued as COSV63321733; called by muse, mutect2, varscan2
- ZNF785 | c.608G>A p.G203D | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67876267; called by muse, mutect2, varscan2
- ZNF91 | c.1354C>T p.H452Y | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV56083526; called by muse, mutect2, varscan2
- ABCC12 | c.510del p.F170Lfs*25 | Frame Shift Del (DEL) | VAF 25/112 reads (22%) | called by mutect2, pindel, varscan2
- ACACA | c.3315A>T p.Q1105H | Missense Mutation (SNP) | VAF 86/242 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- ACSM3 | c.1436_1438del p.D479del | In Frame Del (DEL) | VAF 162/434 reads (37%) | called by pindel, varscan2
- ACSM5 | c.711del p.K238Rfs*24 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | called by mutect2, pindel, varscan2
- ADAM20 | c.2117del p.L706Yfs*? | Frame Shift Del (DEL) | VAF 84/333 reads (25%) | called by mutect2, pindel, varscan2
- AHDC1 | c.2188del p.E730Rfs*2 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, pindel, varscan2
- AKAP12 | c.3420dup p.A1141Sfs*21 | Frame Shift Ins (INS) | VAF 23/69 reads (33%) | called by mutect2, pindel, varscan2
- ARHGAP36 | c.92del p.L31* | Frame Shift Del (DEL) | VAF 45/132 reads (34%) | called by mutect2, pindel, varscan2
- ARID5B | c.3393del p.F1131Lfs*20 | Frame Shift Del (DEL) | VAF 29/116 reads (25%) | called by mutect2, pindel, varscan2
- ATF6B | c.1275_1276del p.P426Sfs*26 | Frame Shift Del (DEL) | VAF 36/103 reads (35%) | called by pindel, varscan2
- ATP1A3 | c.2095del p.Q699Sfs*19 (on ENST00000545399 / NM_001256214.2; = p.Q686Sfs*19 on NM_152296.5) | Frame Shift Del (DEL) | VAF 50/159 reads (31%) | called by mutect2, pindel, varscan2
- BIN1 | c.79_81del p.E27del | In Frame Del (DEL) | VAF 7/12 reads (58%) | called by mutect2, varscan2
- BOD1L1 | c.1707del p.V570* | Frame Shift Del (DEL) | VAF 65/192 reads (34%) | called by mutect2, varscan2
- C21orf58 | c.540del p.T181Rfs*41 | Frame Shift Del (DEL) | VAF 5/11 reads (45%) | called by mutect2, varscan2
- C2orf73 | c.622del p.T208Qfs*11 | Frame Shift Del (DEL) | VAF 18/70 reads (26%) | called by mutect2, pindel, varscan2
- CACNA1F | c.2486del p.G829Vfs*32 | Frame Shift Del (DEL) | VAF 74/302 reads (25%) | called by mutect2, pindel, varscan2
- CDAN1 | c.3025del p.E1009Sfs*23 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | called by mutect2, pindel, varscan2
- CDCA2 | c.258del p.K86Nfs*19 | Frame Shift Del (DEL) | VAF 54/192 reads (28%) | called by mutect2, pindel, varscan2
- CDON | c.403del p.S135Vfs*35 | Frame Shift Del (DEL) | VAF 47/145 reads (32%) | called by mutect2, pindel, varscan2
- CERK | c.222del p.K74Nfs*16 | Frame Shift Del (DEL) | VAF 65/208 reads (31%) | called by mutect2, pindel, varscan2
- COL5A1 | c.5031dup p.S1678Vfs*7 | Frame Shift Ins (INS) | VAF 13/62 reads (21%) | called by mutect2, pindel, varscan2
- COMMD10 | c.467_469del p.P156del | In Frame Del (DEL) | VAF 54/192 reads (28%) | called by pindel, varscan2
- CPEB3 | c.968dup p.R324Pfs*4 | Frame Shift Ins (INS) | VAF 14/31 reads (45%) | called by mutect2, pindel, varscan2
- CXCL9 | c.323del p.K108Rfs*4 | Frame Shift Del (DEL) | VAF 130/467 reads (28%) | called by mutect2, pindel, varscan2
- DAAM1 | c.707dup p.H237Pfs*26 | Frame Shift Ins (INS) | VAF 20/54 reads (37%) | called by mutect2, pindel, varscan2
- DBF4 | c.1223dup p.L409Afs*14 | Frame Shift Ins (INS) | VAF 18/83 reads (22%) | called by mutect2, varscan2
- DLGAP3 | c.1130del p.G377Vfs*91 | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | called by mutect2, pindel, varscan2
- DNAJB11 | c.319del p.S107Hfs*30 | Frame Shift Del (DEL) | VAF 11/123 reads (9%) | called by mutect2, pindel
- ENC1 | c.1496del p.G499Vfs*26 | Frame Shift Del (DEL) | VAF 21/60 reads (35%) | called by mutect2, pindel, varscan2
- ERN2 | c.1274_1277del p.Y425Wfs*25 | Frame Shift Del (DEL) | VAF 17/70 reads (24%) | called by mutect2, pindel, varscan2
- FAM13B | c.2346del p.F782Lfs*18 | Frame Shift Del (DEL) | VAF 111/409 reads (27%) | called by mutect2, pindel, varscan2
- FUBP3 | c.1121del p.X374_splice | Splice Site (DEL) | VAF 7/25 reads (28%) | called by mutect2, pindel, varscan2
- GLB1L | c.1097del p.P366Rfs*5 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | called by mutect2, pindel, varscan2
- GNG13 | c.7_9del p.E3del | In Frame Del (DEL) | VAF 32/86 reads (37%) | called by pindel, varscan2
- GPATCH1 | c.2392del p.E798Kfs*27 | Frame Shift Del (DEL) | VAF 16/66 reads (24%) | called by mutect2, pindel, varscan2
- GPC2 | c.557del p.P186Lfs*32 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | called by mutect2, pindel, varscan2
- GXYLT1 | c.924del p.K308Nfs*4 | Frame Shift Del (DEL) | VAF 33/332 reads (10%) | called by mutect2, pindel
- HCRTR2 | c.366dup p.G123Wfs*41 | Frame Shift Ins (INS) | VAF 72/240 reads (30%) | called by mutect2, pindel, varscan2
- HECW1 | c.3148del p.R1050Efs*13 | Frame Shift Del (DEL) | VAF 60/211 reads (28%) | called by mutect2, pindel, varscan2
- HIP1R | c.190del p.A64Lfs*67 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | called by mutect2, pindel, varscan2
- HIVEP2 | c.554del p.K185Sfs*20 | Frame Shift Del (DEL) | VAF 51/171 reads (30%) | called by mutect2, pindel, varscan2
- KANSL1 | c.2569_2570del p.S857Lfs*3 (on ENST00000574590 / NM_001193465.2; = p.S858Lfs*3 on NM_015443.4) | Frame Shift Del (DEL) | VAF 86/274 reads (31%) | called by pindel, varscan2
- KCNA3 | c.500del p.G167Afs*162 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by pindel, varscan2
- KIAA1109 | c.2544dup p.G849Rfs*3 | Frame Shift Ins (INS) | VAF 69/237 reads (29%) | called by mutect2, pindel, varscan2
- KLF3 | c.677dup p.Q227Afs*37 | Frame Shift Ins (INS) | VAF 47/154 reads (31%) | called by mutect2, varscan2
- MAP4K4 | c.1224_1231dup p.E411Gfs*2 | Frame Shift Ins (INS) | VAF 16/54 reads (30%) | called by mutect2, varscan2
- MGA | c.1840del p.R614Efs*7 | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | called by mutect2, pindel, varscan2
- MRTFA | c.1033del p.D345Tfs*92 | Frame Shift Del (DEL) | VAF 49/161 reads (30%) | called by mutect2, varscan2
- MUC2 | c.1325C>A p.P442H | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- MUC5B | c.12178del p.Q4060Sfs*61 | Frame Shift Del (DEL) | VAF 58/370 reads (16%) | called by pindel, varscan2
- MVK | c.417del p.A141Rfs*18 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | called by mutect2, varscan2
- MYO7B | c.784del p.V262* | Frame Shift Del (DEL) | VAF 13/43 reads (30%) | called by mutect2, pindel, varscan2
- NCOR2 | c.3921del p.K1308Sfs*6 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, pindel, varscan2
- NEIL1 | c.570del p.F191Lfs*20 | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | called by mutect2, pindel, varscan2
- NKAPD1 | c.479del p.K160Sfs*20 (on ENST00000280352 / NM_001082970.2; = p.K161Sfs*20 on NM_018195.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 78/234 reads (33%) | called by mutect2, varscan2
- NOP58 | c.1571del p.K524Rfs*22 | Frame Shift Del (DEL) | VAF 34/122 reads (28%) | called by mutect2, varscan2
- NUP35 | c.933del p.D312Mfs*26 | Frame Shift Del (DEL) | VAF 57/194 reads (29%) | called by mutect2, pindel, varscan2
- NWD1 | c.4513del p.S1505Qfs*28 | Frame Shift Del (DEL) | VAF 11/116 reads (9%) | called by mutect2, pindel, varscan2
- NYNRIN | c.454del p.R152Gfs*8 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | called by mutect2, pindel, varscan2
- OSBPL5 | c.612del p.G206Vfs*16 | Frame Shift Del (DEL) | VAF 21/58 reads (36%) | called by mutect2, pindel, varscan2
- PGR | c.1770_1772del p.F591del | In Frame Del (DEL) | VAF 27/114 reads (24%) | called by pindel, varscan2
- PHF20L1 | c.965del p.N322Mfs*42 | Frame Shift Del (DEL) | VAF 36/98 reads (37%) | called by mutect2, varscan2
- PIGM | c.1240_1242del p.E414del | In Frame Del (DEL) | VAF 37/127 reads (29%) | called by pindel, varscan2
- PLAAT4 | c.482_483del p.K161Sfs*55 | Frame Shift Del (DEL) | VAF 11/102 reads (11%) | called by pindel, varscan2*
- PLPPR4 | c.1723del p.R575Efs*6 | Frame Shift Del (DEL) | VAF 15/38 reads (39%) | called by mutect2, pindel, varscan2
- PLXNA1 | c.3051del p.Q1019Rfs*22 | Frame Shift Del (DEL) | VAF 19/67 reads (28%) | called by mutect2, pindel, varscan2
- PPP1R36 | c.500del p.N167Tfs*12 | Frame Shift Del (DEL) | VAF 65/221 reads (29%) | called by mutect2, pindel, varscan2
- PRRC2A | c.5189del p.P1730Lfs*44 | Frame Shift Del (DEL) | VAF 17/49 reads (35%) | called by mutect2, pindel, varscan2
- PSEN1 | c.899_901del p.E300del | In Frame Del (DEL) | VAF 45/198 reads (23%) | called by mutect2, pindel, varscan2
- RAB11FIP5 | c.1453del p.E485Kfs*28 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | called by mutect2, pindel, varscan2
- ROBO2 | c.3155del p.K1052Rfs*121 | Frame Shift Del (DEL) | VAF 40/144 reads (28%) | called by pindel, varscan2
- ROCK1 | c.4043del p.N1348Ifs*76 | Frame Shift Del (DEL) | VAF 66/229 reads (29%) | called by mutect2, pindel, varscan2
- ROCK1 | c.3770del p.P1257Lfs*3 | Frame Shift Del (DEL) | VAF 62/249 reads (25%) | called by mutect2, pindel, varscan2
- RSRC2 | c.1003del p.R335Gfs*23 | Frame Shift Del (DEL) | VAF 95/337 reads (28%) | called by mutect2, pindel, varscan2
- RUFY2 | c.1241del p.N414Mfs*3 | Frame Shift Del (DEL) | VAF 64/179 reads (36%) | called by mutect2, varscan2
- SELENOV | c.126del p.I43Sfs*4 | Frame Shift Del (DEL) | VAF 9/19 reads (47%) | called by mutect2, pindel, varscan2
- SHKBP1 | c.1214del p.G405Afs*54 | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | called by mutect2, pindel, varscan2
- SI | c.4670dup p.N1557Kfs*8 | Frame Shift Ins (INS) | VAF 47/158 reads (30%) | called by mutect2, pindel, varscan2
- SIN3A | c.450_452del p.I150del | In Frame Del (DEL) | VAF 54/210 reads (26%) | called by pindel, varscan2
- SLC26A8 | c.2525del p.N842Mfs*2 | Frame Shift Del (DEL) | VAF 33/115 reads (29%) | called by mutect2, pindel, varscan2
- SMG1 | c.8598dup p.P2867Sfs*20 | Frame Shift Ins (INS) | VAF 40/118 reads (34%) | called by mutect2, pindel, varscan2
- SND1 | c.853_859del p.T285Sfs*3 | Frame Shift Del (DEL) | VAF 48/130 reads (37%) | called by mutect2, pindel, varscan2
- SNX18 | c.1255del p.D420Tfs*38 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | called by mutect2, varscan2
- SPATA31A1 | c.241C>A p.L81M | Missense Mutation (SNP) | VAF 86/294 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- SPECC1 | c.355_356dup p.S120Gfs*29 | Frame Shift Ins (INS) | VAF 40/107 reads (37%) | called by mutect2, varscan2
- SPIRE2 | c.1501del p.L501Yfs*16 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | called by mutect2, varscan2
- SPTBN5 | c.4185dup p.G1396Rfs*15 | Frame Shift Ins (INS) | VAF 31/99 reads (31%) | called by mutect2, pindel, varscan2
- SRCIN1 | c.2697del p.S900Afs*4 (on ENST00000621492; = p.S866Afs*4 on NM_025248.3) | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | called by mutect2, pindel, varscan2
- TGM6 | c.1078del p.Q360Rfs*99 | Frame Shift Del (DEL) | VAF 13/32 reads (41%) | called by mutect2, pindel, varscan2
- TIRAP | c.20_23del p.L7Qfs*11 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | called by pindel, varscan2
- TLE1 | c.1389del p.D464Tfs*27 | Frame Shift Del (DEL) | VAF 24/114 reads (21%) | called by mutect2, pindel, varscan2
- TMEM168 | c.690dup p.I231Yfs*6 | Frame Shift Ins (INS) | VAF 44/128 reads (34%) | called by mutect2, varscan2
- TMPRSS12 | c.537del p.A180Qfs*2 | Frame Shift Del (DEL) | VAF 35/129 reads (27%) | called by mutect2, pindel, varscan2
- TPP1 | c.496del p.H166Mfs*17 | Frame Shift Del (DEL) | VAF 20/85 reads (24%) | called by mutect2, pindel, varscan2
- TRAF3 | c.1425del p.F475Lfs*20 | Frame Shift Del (DEL) | VAF 55/182 reads (30%) | called by mutect2, pindel, varscan2
- TRAV16 | c.110del p.P37Qfs*4 | Frame Shift Del (DEL) | VAF 48/149 reads (32%) | called by mutect2, pindel, varscan2
- TRIM42 | c.1655dup p.L553Sfs*82 | Frame Shift Ins (INS) | VAF 17/42 reads (40%) | called by mutect2, varscan2
- TRIP11 | c.922del p.M308Wfs*8 | Frame Shift Del (DEL) | VAF 27/90 reads (30%) | called by mutect2, pindel, varscan2
- TWNK | c.928del p.D310Mfs*16 | Frame Shift Del (DEL) | VAF 13/36 reads (36%) | called by mutect2, pindel, varscan2
- UBASH3A | c.650A>G p.H217R | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2
- UBE4B | c.1329_1338+23delinsGCACCAAAGGTAATATGAAATGGATTAACTT p.X443_splice (on ENST00000343090 / NM_001105562.3; = p.X314_splice on NM_006048.5) | Splice Site (DEL) | VAF 9/78 reads (12%) | called by pindel, varscan2*
- UNC13D | c.334dup p.C112Lfs*30 | Frame Shift Ins (INS) | VAF 12/46 reads (26%) | called by mutect2, pindel, varscan2
- USP13 | c.331dup p.R111Kfs*13 | Frame Shift Ins (INS) | VAF 127/460 reads (28%) | called by mutect2, pindel, varscan2
- USP34 | c.8881_8883del p.L2961del | In Frame Del (DEL) | VAF 42/148 reads (28%) | called by pindel, varscan2
- VEZT | c.597del p.K199Nfs*20 | Frame Shift Del (DEL) | VAF 97/322 reads (30%) | called by mutect2, pindel, varscan2
- VPS13B | c.11961del p.S3988Pfs*25 | Frame Shift Del (DEL) | VAF 48/186 reads (26%) | called by mutect2, pindel, varscan2
- WDR44 | c.1625del p.N542Mfs*11 | Frame Shift Del (DEL) | VAF 60/229 reads (26%) | called by mutect2, pindel, varscan2
- WDR49 | c.26del p.K9Sfs*5 (on ENST00000308378 / NM_001366158.1; = p.K350Sfs*5 on NM_001348951.2 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 76/276 reads (28%) | called by mutect2, pindel, varscan2
- ZDHHC3 | c.84dup p.Y29Lfs*13 | Frame Shift Ins (INS) | VAF 24/81 reads (30%) | called by mutect2, pindel, varscan2
- ZNF518B | c.1400del p.N467Ifs*15 | Frame Shift Del (DEL) | VAF 34/110 reads (31%) | called by mutect2, varscan2
- ZNF605 | c.892A>G p.T298A | Missense Mutation (SNP) | VAF 65/210 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCA8 | c.4539G>A p.L1513= | Silent (SNP) | VAF 41/135 reads (30%) | catalogued as COSV52199337; called by muse, mutect2, varscan2
- ACAD10 | c.2886G>A p.Q962= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV58155682; called by muse, mutect2, varscan2
- ACTN1 | c.2514G>A p.G838= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as COSV51990611; called by muse, mutect2, varscan2
- ADAM22 | c.525T>C p.N175= | Silent (SNP) | VAF 14/314 reads (4%) | catalogued as COSV55974481; called by muse, mutect2
- ADGRB3 | c.3261G>A p.L1087= | Silent (SNP) | VAF 27/119 reads (23%) | catalogued as COSV53241125; called by muse, mutect2, varscan2
- AIMP1 | c.114G>A p.L38= | Silent (SNP) | VAF 38/105 reads (36%) | catalogued as COSV63638160; called by muse, mutect2, varscan2
- ALDH3A1 | c.924C>T p.T308= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs779789522, COSV56735038; called by muse, mutect2, varscan2
- ARF1 | c.156C>T p.N52= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs774460920, COSV55254598; called by muse, mutect2, varscan2
- ARMCX1 | c.1119G>A p.L373= | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as COSV65705062; called by muse, mutect2, varscan2
- ARMH4 | c.441T>C p.I147= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV50763397; called by muse, mutect2, varscan2
- ATP13A4 | c.1743C>A p.P581= | Silent (SNP) | VAF 102/283 reads (36%) | catalogued as COSV55068409; called by muse, mutect2, varscan2
- ATP6AP1 | c.345C>T p.S115= | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as rs782743847, COSV62340975; called by muse, mutect2, varscan2
- BICD1 | c.2649T>C p.V883= | Silent (SNP) | VAF 42/123 reads (34%) | catalogued as COSV55677861, COSV55688144; called by muse, mutect2, varscan2
- C17orf98 | c.81C>T p.R27= | Silent (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- C2CD2 | c.858A>G p.A286= | Silent (SNP) | VAF 7/95 reads (7%) | catalogued as COSV61599202; called by muse, mutect2
- CACNA1I | c.5937C>A p.G1979= | Silent (SNP) | VAF 31/79 reads (39%) | catalogued as COSV60805880; called by muse, mutect2, varscan2
- CAPN3 | c.735T>C p.P245= | Silent (SNP) | VAF 6/164 reads (4%) | catalogued as COSV58821368; called by muse, mutect2
- CARS1 | c.2085C>T p.T695= | Silent (SNP) | VAF 32/121 reads (26%) | catalogued as rs572490992, COSV53453315; called by muse, mutect2, varscan2
- CASP8AP2 | c.645T>C p.P215= | Silent (SNP) | VAF 68/207 reads (33%) | catalogued as COSV52746445; called by muse, mutect2, varscan2
- CCKBR | c.870C>T p.S290= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as rs1220407751, COSV58099304; called by muse, mutect2, varscan2
- CDH16 | c.1683C>A p.P561= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as COSV55336144; called by muse, mutect2, varscan2
- CDH5 | c.285C>T p.V95= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as rs373022823, COSV58516407; called by muse, mutect2, varscan2
- CDH5 | c.1200G>A p.A400= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as rs376087780; called by muse, mutect2, varscan2
- CDK5R2 | c.957G>A p.T319= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV56935974; called by muse, mutect2, varscan2
- CHD6 | c.117C>T p.D39= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV58556101; called by muse, mutect2, varscan2
- CHRNB4 | c.978C>A p.T326= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as COSV55715675; called by muse, mutect2, varscan2
- CIPC | c.228G>A p.R76= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as COSV62376879; called by muse, mutect2, varscan2
- CLDN11 | c.231C>T p.Y77= | Silent (SNP) | VAF 31/91 reads (34%) | catalogued as rs367974397; called by muse, mutect2, varscan2
- COL9A1 | c.960C>T p.G320= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV57882362; called by muse, mutect2, varscan2
- CORO1B | c.732G>A p.E244= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV58168953; called by muse, mutect2, varscan2
- CPEB4 | c.1449T>C p.I483= | Silent (SNP) | VAF 34/121 reads (28%) | catalogued as rs781371312, COSV54171215; called by muse, mutect2, varscan2
- CUEDC2 | c.759G>C p.V253= | Silent (SNP) | VAF 61/176 reads (35%) | catalogued as COSV50044645, COSV50069306; called by muse, mutect2, varscan2
- DAPK1 | c.760A>C p.R254= | Silent (SNP) | VAF 29/124 reads (23%) | catalogued as COSV63786685; called by muse, mutect2, varscan2
- DAPK1 | c.2340G>A p.P780= | Silent (SNP) | VAF 37/78 reads (47%) | catalogued as rs545837227, COSV63786689; called by muse, mutect2, varscan2
- DENND10 | c.312C>A p.A104= | Silent (SNP) | VAF 110/349 reads (32%) | catalogued as COSV63857559; called by muse, mutect2, varscan2
- DGKD | c.2688C>T p.I896= (on ENST00000264057 / NM_152879.3; = p.I852= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/64 reads (6%) | catalogued as rs1480812455, COSV51040736, COSV99897644; called by muse, mutect2
- DLST | c.216A>G p.T72= | Silent (SNP) | VAF 153/346 reads (44%) | catalogued as COSV53166063; called by muse, varscan2
- DNAH1 | c.2553C>T p.S851= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV70228193; called by muse, mutect2, varscan2
- DNAH7 | c.7164G>A p.A2388= | Silent (SNP) | VAF 66/190 reads (35%) | catalogued as rs200945065, COSV100418007; called by muse, mutect2, varscan2
- DSEL | c.1014T>C p.G338= | Silent (SNP) | VAF 38/133 reads (29%) | catalogued as COSV59490783; called by muse, mutect2, varscan2
- DYRK1A | c.1260C>A p.T420= | Silent (SNP) | VAF 38/114 reads (33%) | catalogued as COSV58293365; called by muse, mutect2, varscan2
- ECM2 | c.1020G>A p.L340= | Silent (SNP) | VAF 16/202 reads (8%) | catalogued as rs1326388370, COSV60740087; called by muse, mutect2
- EEA1 | c.738A>C p.R246= | Silent (SNP) | VAF 65/177 reads (37%) | catalogued as COSV59284902; called by muse, mutect2, varscan2
- EPHA5 | c.2949A>G p.T983= | Silent (SNP) | VAF 52/165 reads (32%) | catalogued as COSV56640334; called by muse, mutect2, varscan2
- EPRS1 | c.2088G>A p.P696= | Silent (SNP) | VAF 149/429 reads (35%) | catalogued as rs145416177; called by muse, mutect2, varscan2
- EZR | c.414C>T p.N138= | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as COSV61453439; called by muse, mutect2, varscan2
- FAM131B | c.396G>A p.Q132= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as rs1180502781, COSV68125847; called by muse, mutect2, varscan2
- FLNC | c.2310C>T p.Y770= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs374087953; ClinVar: likely benign; called by muse, mutect2, varscan2
- FMNL3 | c.1503C>T p.S501= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs201316473, COSV53300689; called by muse, mutect2, varscan2
- FOXK2 | c.897C>T p.D299= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as COSV58878356; called by muse, mutect2, varscan2
- GLI3 | c.4293G>A p.P1431= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as rs28396689, COSV67887465; called by muse, mutect2, varscan2
- GNAQ | c.693G>A p.A231= | Silent (SNP) | VAF 72/232 reads (31%) | catalogued as rs760629825, COSV54111537; called by muse, mutect2, varscan2
- GPER1 | c.672C>T p.I224= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs778619173, COSV52468637; called by muse, mutect2
- H2AC15 | c.231C>T p.T77= | Silent (SNP) | VAF 50/128 reads (39%) | catalogued as COSV57585468; called by muse, mutect2, varscan2
- HECTD1 | c.1182T>C p.D394= | Silent (SNP) | VAF 46/164 reads (28%) | catalogued as COSV67945914; called by muse, mutect2, varscan2
- HIF1A | c.1005T>C p.I335= | Silent (SNP) | VAF 56/176 reads (32%) | catalogued as COSV60188890; called by muse, mutect2, varscan2
- HLA-DOB | c.135C>T p.N45= | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as rs374787208; called by muse, mutect2, varscan2
- HOOK1 | c.1380A>G p.P460= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as rs761141626, COSV64618503; called by muse, mutect2, varscan2
- HOOK3 | c.909C>T p.I303= | Silent (SNP) | VAF 52/151 reads (34%) | catalogued as rs561721523, COSV56881523; called by muse, mutect2, varscan2
- HOXB3 | c.1203C>T p.C401= | Silent (SNP) | VAF 94/266 reads (35%) | catalogued as COSV57486501; called by muse, mutect2, varscan2
- HS6ST2 | c.573G>A p.P191= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV63712289; called by muse, mutect2, varscan2
- HYAL3 | c.177C>T p.A59= | Silent (SNP) | VAF 6/127 reads (5%) | catalogued as COSV56497342; called by muse, mutect2
- IGF2R | c.1812T>C p.G604= | Silent (SNP) | VAF 8/124 reads (6%) | catalogued as COSV63628302; called by muse, mutect2
- IKZF2 | c.237C>T p.S79= | Silent (SNP) | VAF 63/197 reads (32%) | catalogued as rs1219850399, COSV59577842; called by muse, mutect2, varscan2
- IL4I1 | c.63C>A p.S21= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as COSV62009514; called by muse, mutect2, varscan2
- IQGAP1 | c.1746G>A p.T582= | Silent (SNP) | VAF 60/170 reads (35%) | catalogued as rs201387133; called by muse, mutect2, varscan2
- ITGB3 | c.150C>T p.A50= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV71383864; called by muse, mutect2, varscan2
- ITPRIPL1 | c.1242C>T p.P414= (on ENST00000439118 / NM_001008949.3; = p.P422= on NM_178495.6) | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs754055738, COSV63152688; called by muse, mutect2, varscan2
- ITSN2 | c.165G>A p.P55= | Silent (SNP) | VAF 12/174 reads (7%) | catalogued as rs1390891334, COSV61943401; called by muse, mutect2
- KCTD7 | c.735G>A p.P245= (on ENST00000275532; = p.V259M on NM_153033.5) | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as COSV51876632; called by muse, mutect2, varscan2
- KIF2B | c.1188T>C p.C396= | Silent (SNP) | VAF 40/130 reads (31%) | catalogued as COSV52129423; called by muse, mutect2, varscan2
- KLHDC4 | c.1365C>T p.D455= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs1255858544, COSV54507372; called by muse, mutect2, varscan2
- KLHL9 | c.1104A>T p.T368= | Silent (SNP) | VAF 43/141 reads (30%) | catalogued as COSV62921461; called by muse, mutect2, varscan2
- KPNA2 | c.1068G>A p.T356= | Silent (SNP) | VAF 7/154 reads (5%) | catalogued as rs374422131; called by muse, mutect2
- L1CAM | c.1722G>A p.G574= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs2857756, COSV62827750; called by muse, mutect2, varscan2
- LMNB1 | c.651C>T p.N217= | Silent (SNP) | VAF 37/100 reads (37%) | catalogued as rs762491977, COSV54397490; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRCH3 | c.1236G>A p.R412= | Silent (SNP) | VAF 44/172 reads (26%) | catalogued as COSV58391205; called by muse, mutect2, varscan2
- LRP1 | c.10971C>T p.D3657= | Silent (SNP) | VAF 32/64 reads (50%) | catalogued as rs372991872; called by muse, mutect2, varscan2
- MAN2A2 | c.2412C>A p.T804= | Silent (SNP) | VAF 40/107 reads (37%) | catalogued as COSV64637943; called by muse, mutect2, varscan2
- MAP3K10 | c.330C>T p.G110= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV53421716; called by muse, mutect2, varscan2
- MAST3 | c.2424C>T p.P808= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs55972498; called by mutect2, varscan2
- MEGF10 | c.1914C>T p.C638= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs1490813867, COSV57248075; called by muse, mutect2, varscan2
- MID2 | c.297G>A p.L99= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as rs750882971, COSV53308701; called by muse, mutect2, varscan2
- MLLT3 | c.1059G>A p.P353= | Silent (SNP) | VAF 92/227 reads (41%) | catalogued as rs374461240; called by muse, mutect2, varscan2
- MMP11 | c.1098C>T p.D366= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs766288227, COSV53156010; called by muse, mutect2, varscan2
- MORN5 | c.363C>T p.Y121= | Silent (SNP) | VAF 59/194 reads (30%) | catalogued as rs780115896, COSV65648538; called by muse, mutect2, varscan2
- MROH9 | c.1383G>A p.L461= | Silent (SNP) | VAF 48/317 reads (15%) | catalogued as COSV63010871; called by muse, mutect2, varscan2
- MYCL | c.612C>T p.H204= | Silent (SNP) | VAF 10/126 reads (8%) | catalogued as COSV65693236; called by muse, mutect2
- MYH7 | c.4020C>T p.C1340= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs374499515; called by muse, mutect2, varscan2
- MYLK2 | c.321C>T p.S107= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs757763288, COSV65658929; called by muse, mutect2, varscan2
- MYOM2 | c.1791G>T p.S597= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as COSV50705070, COSV50708550; called by muse, mutect2, varscan2
- NAALADL2 | c.1467A>C p.R489= | Silent (SNP) | VAF 53/143 reads (37%) | catalogued as COSV69155365; called by muse, mutect2, varscan2
- NAV3 | c.3372G>A p.V1124= | Silent (SNP) | VAF 9/95 reads (9%) | catalogued as COSV57074549; called by muse, mutect2
- NCAPG | c.606T>C p.C202= | Silent (SNP) | VAF 54/162 reads (33%) | catalogued as COSV52269632; called by muse, mutect2, varscan2
- NFATC2 | c.1602C>T p.D534= | Silent (SNP) | VAF 45/120 reads (38%) | catalogued as COSV65354990; called by muse, mutect2, varscan2
- NFKB2 | c.1602G>A p.A534= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs764692852, COSV50044644; called by muse, mutect2, varscan2
- NHS | c.3879T>C p.V1293= | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as COSV66273818; called by muse, mutect2, varscan2
- NRIP2 | c.840C>T p.G280= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV57389467; called by muse, mutect2, varscan2
- NUBP2 | c.103C>T p.L35= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs780882513, COSV51905468; called by muse, mutect2, varscan2
- OGFOD2 | c.387G>A p.R129= (on ENST00000228922 / NM_001304833.1; = p.R69= on NM_024623.3) | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as COSV57441532; called by muse, mutect2, varscan2
- OLFM4 | c.993A>C p.T331= | Silent (SNP) | VAF 37/122 reads (30%) | catalogued as rs1300381575, COSV54576833; called by muse, varscan2
- PAQR5 | c.795G>A p.T265= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as rs570148662, COSV61817308; called by muse, mutect2
- PCBP3 | c.1074C>T p.N358= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs375088297; called by muse, mutect2, varscan2
- PCDHA3 | c.1590G>A p.L530= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs1554122364, COSV63540503; called by muse, mutect2, varscan2
- PCDHA3 | c.1758T>C p.G586= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV63540506; called by muse, mutect2, varscan2
- PCDHA5 | c.1083C>T p.D361= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV65351349; called by muse, mutect2, varscan2
- PHC1 | c.1383T>G p.P461= | Silent (SNP) | VAF 48/206 reads (23%) | catalogued as COSV70417793; called by muse, mutect2, varscan2
- PKP1 | c.1755C>T p.G585= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as rs1260531497, COSV55820776; called by muse, mutect2
- PKP3 | c.1209C>T p.N403= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as rs778602530, COSV58986780; called by muse, mutect2, varscan2
- PLCXD2 | c.351G>A p.V117= | Silent (SNP) | VAF 32/112 reads (29%) | catalogued as COSV67339342; called by muse, mutect2, varscan2
- PMEPA1 | c.492C>A p.P164= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV55692909; called by muse, mutect2
- POLM | c.681A>G p.R227= | Silent (SNP) | VAF 40/142 reads (28%) | catalogued as COSV54242299; called by muse, mutect2, varscan2
- PPAT | c.378A>G p.V126= | Silent (SNP) | VAF 66/196 reads (34%) | catalogued as COSV51703786; called by muse, mutect2, varscan2
- PRX | c.2430G>A p.G810= | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as COSV52529340; called by muse, mutect2, varscan2
- PSAT1 | c.682C>T p.L228= | Silent (SNP) | VAF 69/188 reads (37%) | catalogued as COSV61302424; called by muse, varscan2
- RASGRP1 | c.2118T>C p.L706= | Silent (SNP) | VAF 64/176 reads (36%) | catalogued as rs1237544766, COSV60364738; called by muse, mutect2, varscan2
- RBM4 | c.912C>T p.Y304= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs777866630, COSV59518545; called by muse, mutect2, varscan2
- RCN3 | c.867C>T p.S289= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs370574318; called by muse, mutect2, varscan2
- RFX4 | c.1302C>T p.F434= (on ENST00000392842 / NM_213594.3; = p.F340= on NM_032491.6) | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as rs144713941; called by muse, mutect2, varscan2
- RICTOR | c.474T>C p.A158= | Silent (SNP) | VAF 32/132 reads (24%) | catalogued as rs1274302499, COSV57120654; called by muse, mutect2, varscan2
- RNF32 | c.994C>T p.L332= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as COSV58731995; called by muse, mutect2, varscan2
- RPAP2 | c.724C>T p.L242= | Silent (SNP) | VAF 44/260 reads (17%) | catalogued as COSV72509139; called by muse, mutect2, varscan2
- RTL8A | c.180C>T p.N60= | Silent (SNP) | VAF 28/98 reads (29%) | catalogued as COSV66188514; called by muse, mutect2, varscan2
- SAMD11 | c.162C>T p.S54= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs777848064, COSV59704210; called by muse, mutect2, varscan2
61 further variants in this file (0 protein-altering or splice-affecting, 46 silent, 15 other) are not listed here.
